Somatic mutation profile of cancer-model specimen HCM-BROD-0954-C34-85A (3D Organoid, passage 7; aliquot HCM-BROD-0954-C34-85A-01D-A87L-36), derived from the primary tumor of HCMI case HCM-BROD-0954-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 66.3 years (24,222 days).
Specimen HCM-BROD-0954-C34-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6cd442d3-02b6-4650-9752-aeb88482d9d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0954-C34-10A (Blood Derived Normal), aliquot HCM-BROD-0954-C34-10A-01D-A87L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5cbe3997-5683-4b2a-8389-957111ed4cf6

The open-access MAF lists 832 somatic variants for this specimen: 596 protein-altering or splice-affecting, 198 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 526, Silent 198, Nonsense Mutation 40, Intron 23, Frame Shift Del 17, Frame Shift Ins 7, RNA 4, 5'UTR 4, 3'UTR 4, Splice Site 3, 5'Flank 3, Splice Region 2.

Variants (750 of 832; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN1B | c.285dup p.K96Qfs*29 | Frame Shift Ins (INS) | VAF 129/646 reads (20%) | catalogued as rs1555085575, COSV99963918; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.423C>G p.C141W | Missense Mutation (SNP) | VAF 492/494 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519977, COSV52671863, COSV52706449, COSV52741627, COSV52827803; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADAMTS20 | c.2267G>T p.G756V | Missense Mutation (SNP) | VAF 228/455 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1211908861; called by muse, mutect2, varscan2
- ADCY8 | c.3280G>T p.G1094C | Missense Mutation (SNP) | VAF 234/481 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53895143, COSV53925697; called by muse, varscan2
- AHNAK2 | c.7101C>G p.S2367R | Missense Mutation (SNP) | VAF 127/128 reads (99%) | SIFT tolerated (0.2); PolyPhen benign (0.238); catalogued as COSV100318347; called by muse, mutect2
- AK7 | c.58G>T p.V20L | Missense Mutation (SNP) | VAF 213/213 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as rs1281292214; called by muse, mutect2, varscan2
- ANK2 | c.2899G>T p.G967C | Missense Mutation (SNP) | VAF 115/115 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52176977; called by muse, mutect2, varscan2
- ANO3 | c.812C>A p.P271Q | Missense Mutation (SNP) | VAF 302/302 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99881410; called by muse, mutect2, varscan2
- ANO4 | c.2584C>A p.R862S (on ENST00000392977 / NM_001286615.2; = p.R827S on NM_178826.4) | Missense Mutation (SNP) | VAF 293/568 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54595545; called by muse, mutect2, varscan2
- APOA4 | c.480C>G p.Y160* | Nonsense Mutation (SNP) | VAF 214/587 reads (36%) | catalogued as COSV100759252, COSV63360358; called by muse, mutect2, varscan2
- APOB | c.2410C>A p.R804S | Missense Mutation (SNP) | VAF 273/423 reads (65%) | SIFT tolerated (0.07); PolyPhen benign (0.316); catalogued as COSV99264638; called by muse, mutect2, varscan2
- ARHGEF12 | c.4013G>C p.R1338P | Missense Mutation (SNP) | VAF 239/328 reads (73%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV63105097, COSV63107934; called by muse, mutect2, varscan2
- ARHGEF5 | c.4723C>T p.R1575C | Missense Mutation (SNP) | VAF 127/235 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs764608154, COSV50207993; called by muse, mutect2, varscan2
- ASL | c.301G>C p.G101R | Missense Mutation (SNP) | VAF 122/474 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59189417; called by muse, mutect2, varscan2
- B3GNT8 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 140/617 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.448); catalogued as rs758478385, COSV99524451; called by muse, mutect2, varscan2
- BPI | c.422G>T p.G141V (on ENST00000262865; = p.G137V on NM_001725.3) | Missense Mutation (SNP) | VAF 226/346 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs193123151; called by muse, mutect2, varscan2
- BPIFB1 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 176/587 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.011); catalogued as rs776047607, COSV53606515; called by muse, mutect2, varscan2
- BTNL2 | c.1294G>C p.D432H | Missense Mutation (SNP) | VAF 297/448 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV66630896; called by muse, mutect2, varscan2
- C1QTNF6 | c.236G>T p.R79L | Missense Mutation (SNP) | VAF 113/374 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV55396338; called by muse, mutect2, varscan2
- CACNA2D1 | c.1921C>T p.Q641* (on ENST00000356253 / NM_001366867.1; = p.Q622* on NM_000722.4) | Nonsense Mutation (SNP) | VAF 116/297 reads (39%) | catalogued as rs1554338711; called by muse, mutect2, varscan2
- CALN1 | c.643C>G p.R215G (on ENST00000329008 / NM_001017440.3; = p.R257G on NM_031468.4) | Missense Mutation (SNP) | VAF 136/315 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV61119545; called by muse, mutect2, varscan2
- CARS2 | c.247T>C p.Y83H | Missense Mutation (SNP) | VAF 121/265 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1566364834; called by muse, mutect2, varscan2
- CASQ1 | c.693C>G p.F231L | Missense Mutation (SNP) | VAF 218/220 reads (99%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.495); catalogued as COSV63624473; called by muse, mutect2, varscan2
- CCDC74A | c.1030C>A p.R344S | Missense Mutation (SNP) | VAF 255/387 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV54605064; called by muse, mutect2, varscan2
- CD33 | c.270C>A p.F90L | Missense Mutation (SNP) | VAF 165/636 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV51805365; called by muse, mutect2, varscan2
- CFAP47 | c.8345-1G>T p.X2782_splice | Splice Site (SNP) | VAF 132/258 reads (51%) | catalogued as rs1556011615; called by mutect2, varscan2
- CHRNA6 | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 272/498 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1486057766; called by muse, mutect2, varscan2
- CHST8 | c.1093C>A p.P365T | Missense Mutation (SNP) | VAF 168/730 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99381259; called by muse, mutect2, varscan2
- CHST8 | c.1094C>A p.P365Q | Missense Mutation (SNP) | VAF 160/684 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749617284; called by mutect2, varscan2
- CLCN4 | c.1321G>A p.A441T | Missense Mutation (SNP) | VAF 376/731 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.088); catalogued as rs1280248831; called by muse, mutect2, varscan2
- CNTNAP5 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 210/338 reads (62%) | SIFT tolerated (0.26); PolyPhen benign (0.136); catalogued as rs760438818, COSV70470252; called by muse, mutect2, varscan2
- COL14A1 | c.1325C>A p.A442D | Missense Mutation (SNP) | VAF 89/406 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.255); catalogued as rs1453839560; called by muse, mutect2, varscan2
- COL3A1 | c.1150-1G>A p.X384_splice | Splice Site (SNP) | VAF 175/301 reads (58%) | catalogued as CS971681, COSV58590329; called by muse, mutect2, varscan2
- CXADR | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 139/270 reads (51%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1431285610; called by muse, mutect2, varscan2
- CYLC1 | c.1774G>T p.G592W | Missense Mutation (SNP) | VAF 291/430 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61416019; called by muse, mutect2, varscan2
- DHDH | c.340C>T p.R114* | Nonsense Mutation (SNP) | VAF 380/502 reads (76%) | catalogued as rs757425465, COSV99668451; called by muse, mutect2, varscan2
- DLX5 | c.158del p.G53Efs*28 | Frame Shift Del (DEL) | VAF 222/558 reads (40%) | catalogued as COSV56034256; called by mutect2, pindel, varscan2
- DNAH10 | c.12919G>T p.V4307L (on ENST00000409039; = p.V4246L on NM_207437.3) | Missense Mutation (SNP) | VAF 315/699 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV99435262; called by muse, mutect2, varscan2
- DPPA2 | c.601G>C p.A201P | Missense Mutation (SNP) | VAF 298/299 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); catalogued as COSV101524730; called by muse, mutect2, varscan2
- DSC2 | c.2635G>A p.D879N | Missense Mutation (SNP) | VAF 112/502 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as COSV51864031; called by muse, mutect2, varscan2
- DSE | c.2752A>G p.M918V | Missense Mutation (SNP) | VAF 139/434 reads (32%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); catalogued as rs780791978, COSV59064011; called by muse, mutect2, varscan2
- DSEL | c.1043A>C p.Y348S | Missense Mutation (SNP) | VAF 210/755 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59494128; called by muse, mutect2, varscan2
- DST | c.8275C>A p.P2759T | Missense Mutation (SNP) | VAF 83/292 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.066); catalogued as rs372727091; called by muse, mutect2
- DUSP1 | c.319G>T p.G107C | Missense Mutation (SNP) | VAF 208/209 reads (100%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.749); catalogued as rs1020876628; called by muse, mutect2, varscan2
- EFHD2 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 280/440 reads (64%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.484); catalogued as rs1296899812; called by muse, mutect2, varscan2
- EIF2AK4 | c.4273A>G p.T1425A | Missense Mutation (SNP) | VAF 76/302 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs1221664821; called by muse, mutect2, varscan2
- EPHA5 | c.1636G>T p.A546S | Missense Mutation (SNP) | VAF 282/283 reads (100%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as COSV56678728; called by muse, mutect2, varscan2
- ERO1B | c.88G>A p.V30I | Missense Mutation (SNP) | VAF 130/360 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV59241430; called by muse, mutect2, varscan2
- ERVV-1 | c.878C>A p.T293K | Missense Mutation (SNP) | VAF 389/605 reads (64%) | SIFT tolerated (0.98); PolyPhen benign (0.137); catalogued as rs745614848; called by muse, mutect2, varscan2
- ESPL1 | c.4053C>A p.D1351E | Missense Mutation (SNP) | VAF 135/586 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV57762754; called by muse, mutect2, varscan2
- ETV1 | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 117/595 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54148151; called by muse, mutect2, varscan2
- EXOC1 | c.1670G>T p.G557V | Missense Mutation (SNP) | VAF 81/211 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV62121420; called by muse, mutect2, varscan2
- EXT1 | c.1237G>T p.E413* | Nonsense Mutation (SNP) | VAF 139/707 reads (20%) | catalogued as CD053568; called by muse, mutect2, varscan2
- FAM47B | c.1520G>T p.R507M | Missense Mutation (SNP) | VAF 457/919 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV61454222; called by muse, mutect2, varscan2
- FAT3 | c.1279G>T p.G427C | Missense Mutation (SNP) | VAF 239/352 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758156812, COSV53130348; called by muse, mutect2, varscan2
- FGF21 | c.435C>A p.H145Q | Missense Mutation (SNP) | VAF 170/807 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.062); catalogued as rs1371086194; called by muse, mutect2, varscan2
- FGL1 | c.54G>T p.R18S | Missense Mutation (SNP) | VAF 110/384 reads (29%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV67713231; called by muse, mutect2, varscan2
- FHOD3 | c.2531C>A p.P844H (on ENST00000359247 / NM_001281739.3; = p.P861H on NM_025135.5) | Missense Mutation (SNP) | VAF 127/368 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV57187524; called by muse, mutect2, varscan2
- FLI1 | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 303/465 reads (65%) | catalogued as COSV99857948; called by muse, mutect2, varscan2
- FMNL3 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 227/474 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs769025035, COSV53299199; called by muse, mutect2, varscan2
- FNDC7 | c.995C>T p.T332I | Missense Mutation (SNP) | VAF 210/376 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1408368566; called by muse, mutect2, varscan2
- FOCAD | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 81/211 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs141558162; called by muse, mutect2, varscan2
- FREM2 | c.4986G>T p.K1662N | Missense Mutation (SNP) | VAF 105/215 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.177); catalogued as COSV99746760; called by muse, mutect2, varscan2
- FSCB | c.874C>T p.Q292* | Nonsense Mutation (SNP) | VAF 276/581 reads (48%) | catalogued as COSV61218660; called by muse, mutect2, varscan2
- FYN | c.44C>T p.T15M | Missense Mutation (SNP) | VAF 129/354 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.097); catalogued as rs140762956, COSV57614854; called by muse, mutect2, varscan2
- GANAB | c.589G>T p.D197Y | Missense Mutation (SNP) | VAF 109/434 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs772866333; called by muse, mutect2, varscan2
- GAPVD1 | c.2343G>T p.K781N | Missense Mutation (SNP) | VAF 162/242 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV99783218; called by mutect2, varscan2
- GBP4 | c.503G>T p.R168M | Missense Mutation (SNP) | VAF 89/189 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV63252871; called by muse, mutect2, varscan2
- GK2 | c.848G>T p.C283F | Missense Mutation (SNP) | VAF 272/272 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1171405467, COSV62627274; called by muse, mutect2, varscan2
- GNAS | c.466C>A p.P156T | Missense Mutation (SNP) | VAF 146/408 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.554); catalogued as COSV58347186; called by muse, mutect2, varscan2
- GRM4 | c.587C>A p.S196Y | Missense Mutation (SNP) | VAF 195/505 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65216087; called by muse, mutect2, varscan2
- GTF3C1 | c.1169G>T p.R390L | Missense Mutation (SNP) | VAF 162/408 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs755821649; called by muse, mutect2, varscan2
- GUCY1A2 | c.1681G>C p.D561H | Missense Mutation (SNP) | VAF 81/235 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56496871; called by muse, mutect2, varscan2
- H3C12 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 143/221 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.164); catalogued as rs897588547; called by muse, mutect2, varscan2
- HCN4 | c.1169G>T p.R390L | Missense Mutation (SNP) | VAF 78/217 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56084696; called by muse, mutect2, varscan2
- HOXA7 | c.467C>T p.T156M | Missense Mutation (SNP) | VAF 533/853 reads (62%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs559344881, COSV54217061; called by muse, mutect2, varscan2
- IFT52 | c.472G>T p.G158* | Nonsense Mutation (SNP) | VAF 67/263 reads (25%) | catalogued as COSV100887560; called by muse, mutect2, varscan2
- IL18RAP | c.537C>G p.S179R | Missense Mutation (SNP) | VAF 215/333 reads (65%) | SIFT tolerated (0.13); PolyPhen benign (0.412); catalogued as rs1280903506; called by muse, mutect2, varscan2
- IL9 | c.68C>A p.T23N | Missense Mutation (SNP) | VAF 65/170 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as rs923834612; called by muse, mutect2, varscan2
- ITGA5 | c.480C>A p.Y160* | Nonsense Mutation (SNP) | VAF 181/392 reads (46%) | catalogued as COSV53218987; called by muse, mutect2, varscan2
- ITGAD | c.231C>G p.I77M | Missense Mutation (SNP) | VAF 136/407 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV66757758; called by muse, mutect2, varscan2
- JADE3 | c.1561G>T p.G521W | Missense Mutation (SNP) | VAF 163/346 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54470100; called by muse, mutect2, varscan2
- JCAD | c.2054G>C p.R685P | Missense Mutation (SNP) | VAF 295/445 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV64760163; called by muse, mutect2, varscan2
- KCNH6 | c.2626C>A p.P876T | Missense Mutation (SNP) | VAF 358/566 reads (63%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.079); catalogued as COSV59007020; called by muse, mutect2
- KEAP1 | c.1802G>C p.R601P | Missense Mutation (SNP) | VAF 434/434 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV50266847; called by muse, mutect2, varscan2
- KIF17 | c.1321A>G p.M441V | Missense Mutation (SNP) | VAF 287/452 reads (63%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as rs1317971715; called by muse, mutect2, varscan2
- KIR3DL3 | c.1036T>C p.W346R | Missense Mutation (SNP) | VAF 96/413 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as rs752114211, COSV52547447; called by muse, mutect2, varscan2
- KLHL24 | c.704G>T p.R235L | Missense Mutation (SNP) | VAF 84/208 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.495); catalogued as COSV54428909; called by mutect2, varscan2
- KRT75 | c.1426A>T p.T476S | Missense Mutation (SNP) | VAF 169/385 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV52874820; called by muse, mutect2
- LAMA4 | c.919G>C p.A307P (on ENST00000230538 / NM_001105206.3; = p.A300P on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 167/491 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV57893745, COSV57906568; called by muse, mutect2, varscan2
- LIME1 | c.98G>T p.R33M | Missense Mutation (SNP) | VAF 95/316 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1372812557; called by muse, mutect2, varscan2
- LIN28B | c.376G>A p.G126R | Missense Mutation (SNP) | VAF 114/189 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as COSV61496593, COSV61497498; called by muse, mutect2, varscan2
- LONRF1 | c.1127C>T p.P376L | Missense Mutation (SNP) | VAF 147/364 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs760751768; called by muse, mutect2, varscan2
- LPCAT2 | c.530G>T p.R177I | Missense Mutation (SNP) | VAF 199/302 reads (66%) | SIFT deleterious (0.04); PolyPhen benign (0.305); catalogued as rs775039999; called by muse, mutect2, varscan2
- LRP1 | c.5843G>T p.R1948L | Missense Mutation (SNP) | VAF 280/616 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV99674143; called by muse, mutect2, varscan2
- LRP1B | c.10378C>A p.P3460T | Missense Mutation (SNP) | VAF 247/385 reads (64%) | SIFT tolerated (0.08); PolyPhen benign (0.272); catalogued as COSV101257804; called by muse, mutect2, varscan2
- LRPPRC | c.56G>C p.R19P | Missense Mutation (SNP) | VAF 158/416 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.32); catalogued as rs1242185696; called by muse, mutect2, varscan2
- LRRC40 | c.1329G>T p.R443S | Missense Mutation (SNP) | VAF 98/158 reads (62%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.702); catalogued as rs1346885549, COSV100918861, COSV100918878; called by muse, mutect2, varscan2
- LUC7L | c.614G>T p.R205L | Missense Mutation (SNP) | VAF 237/238 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1232659702; called by muse, mutect2, varscan2
- MAGEB10 | c.427C>G p.Q143E | Missense Mutation (SNP) | VAF 376/728 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as rs759188030; called by muse, mutect2, varscan2
- MAGI3 | c.760G>T p.A254S | Missense Mutation (SNP) | VAF 77/166 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs374232138, COSV56829029; called by muse, mutect2, varscan2
- MAPK8 | c.498G>T p.K166N | Missense Mutation (SNP) | VAF 227/227 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100827582; called by muse, mutect2, varscan2
- MFAP5 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 122/444 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1433247449; called by muse, mutect2, varscan2
- MFSD3 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 119/1029 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.594); catalogued as rs751492931; called by muse, mutect2, varscan2
- MMUT | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 149/476 reads (31%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.275); catalogued as CM941071, COSV104389442, COSV99222365; called by muse, mutect2, varscan2
- MPEG1 | c.1220C>A p.T407N | Missense Mutation (SNP) | VAF 256/387 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57091163; called by muse, mutect2, varscan2
- MSC | c.10G>T p.G4C | Missense Mutation (SNP) | VAF 127/300 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV57696286; called by muse, mutect2, varscan2
- MTCL1 | c.2320G>A p.G774R (on ENST00000306329 / NM_001378206.1; = p.G414R on NM_015210.4) | Missense Mutation (SNP) | VAF 639/792 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60410936; called by muse, mutect2, varscan2
- MTIF3 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 136/331 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs1468376785; called by muse, mutect2, varscan2
- MYLK2 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 156/547 reads (29%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs377211647; called by muse, mutect2, varscan2
- MYO16 | c.521C>A p.S174Y | Missense Mutation (SNP) | VAF 113/268 reads (42%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as COSV99194984; called by muse, mutect2, varscan2
- NCOA3 | c.653G>T p.R218L | Missense Mutation (SNP) | VAF 327/478 reads (68%) | SIFT tolerated (0.06); PolyPhen benign (0.093); catalogued as rs1200320359, COSV59069121; called by muse, mutect2, varscan2
- NELL1 | c.1577G>A p.G526D | Missense Mutation (SNP) | VAF 196/196 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54301006; called by muse, mutect2, varscan2
- NEURL1 | c.860C>A p.P287Q | Missense Mutation (SNP) | VAF 241/246 reads (98%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as rs1191556438; called by muse, varscan2
- NLRP12 | c.2409G>A p.M803I | Missense Mutation (SNP) | VAF 238/335 reads (71%) | SIFT tolerated (0.14); PolyPhen benign (0.049); catalogued as rs1382727542; called by muse, mutect2
- NPAP1 | c.1150G>T p.D384Y | Missense Mutation (SNP) | VAF 213/357 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV61508831; called by muse, mutect2, varscan2
- NPAP1 | c.3286C>T p.Q1096* | Nonsense Mutation (SNP) | VAF 134/445 reads (30%) | catalogued as rs1406443783; called by muse, mutect2, varscan2
- NPAS3 | c.234G>C p.L78F (on ENST00000356141 / NM_001164749.2; = p.L48F on NM_022123.3) | Missense Mutation (SNP) | VAF 253/528 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58097916; called by muse, mutect2, varscan2
- NRG1 | c.751A>G p.I251V (on ENST00000405005 / NM_013964.5; = p.I256V on NM_013956.5) | Missense Mutation (SNP) | VAF 252/520 reads (48%) | SIFT tolerated (0.98); PolyPhen possibly damaging (0.506); catalogued as rs778488862, COSV55157851; called by muse, mutect2
- NT5DC4 | c.11G>A p.W4* | Nonsense Mutation (SNP) | VAF 163/517 reads (32%) | catalogued as rs1452441364; called by muse, mutect2, varscan2
- OR10S1 | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 316/477 reads (66%) | catalogued as rs1307904737; called by muse, mutect2, varscan2
- OR2M4 | c.70C>T p.H24Y | Missense Mutation (SNP) | VAF 323/323 reads (100%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.52); catalogued as rs745730324; called by muse, mutect2, varscan2
- OR4C15 | c.453G>C p.M151I (on ENST00000314644; = p.M97I on NM_001001920.2) | Missense Mutation (SNP) | VAF 142/498 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.025); catalogued as COSV58951556; called by muse, mutect2, varscan2
- OR5H14 | c.643C>A p.L215I | Missense Mutation (SNP) | VAF 109/110 reads (99%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.571); catalogued as COSV71193776; called by muse, mutect2, varscan2
- OSR2 | c.616C>A p.H206N | Missense Mutation (SNP) | VAF 165/337 reads (49%) | SIFT tolerated (0.36); PolyPhen benign (0.115); catalogued as COSV52559238; called by muse, mutect2, varscan2
- OTOGL | c.5933C>G p.P1978R (on ENST00000547103; = p.P1969R on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 241/558 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs777681714; called by muse, mutect2
- PAPOLG | c.1970G>A p.R657K | Missense Mutation (SNP) | VAF 63/275 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.058); catalogued as COSV53184155; called by muse, mutect2
- PCDH11X | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 125/356 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53462647, COSV53483839; called by muse, mutect2, varscan2
- PCDHA4 | c.123C>A p.H41Q | Missense Mutation (SNP) | VAF 413/414 reads (100%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV100793772; called by muse, mutect2, varscan2
- PDCD11 | c.5197G>A p.A1733T | Missense Mutation (SNP) | VAF 10/272 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV53297276; called by muse, mutect2
- PDE1A | c.1355C>G p.T452S | Missense Mutation (SNP) | VAF 135/239 reads (56%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV59536418; called by muse, mutect2, varscan2
- PDE3A | c.1291C>A p.P431T | Missense Mutation (SNP) | VAF 242/454 reads (53%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.803); catalogued as rs375387597; called by muse, mutect2, varscan2
- PDE6C | c.1406C>A p.S469Y | Missense Mutation (SNP) | VAF 130/131 reads (99%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as COSV65115050; called by muse, mutect2, varscan2
- PDPR | c.2354G>T p.W785L | Missense Mutation (SNP) | VAF 231/372 reads (62%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.845); catalogued as COSV55349327; called by muse, mutect2, varscan2
- PDZD2 | c.637G>T p.G213W | Missense Mutation (SNP) | VAF 422/766 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99223650; called by muse, mutect2, varscan2
- PEAK3 | c.579_580del p.H194Rfs*45 | Frame Shift Del (DEL) | VAF 245/388 reads (63%) | catalogued as rs1208761904; called by pindel, varscan2
- PGAP4 | c.1184G>T p.R395L | Missense Mutation (SNP) | VAF 226/360 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66387423; called by muse, mutect2
- PHLDB3 | c.1910del p.N637Tfs*56 | Frame Shift Del (DEL) | VAF 83/433 reads (19%) | catalogued as rs779273543; called by mutect2, pindel, varscan2
- PIK3CG | c.86C>A p.A29E | Missense Mutation (SNP) | VAF 307/308 reads (100%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.065); catalogued as COSV100783093; called by muse, mutect2, varscan2
- PKLR | c.336G>T p.M112I | Missense Mutation (SNP) | VAF 158/509 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61360867; called by muse, mutect2, varscan2
- PNLIPRP2 | c.259C>G p.R87G | Missense Mutation (SNP) | VAF 279/419 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53944274; called by muse, mutect2, varscan2
- PODN | c.838G>C p.V280L (on ENST00000395871; = p.V232L on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 145/505 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.183); catalogued as COSV57014226; called by muse, mutect2, varscan2
- POLE | c.369G>T p.K123N | Missense Mutation (SNP) | VAF 219/513 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1328407908; called by muse, mutect2, varscan2
- POTEE | c.2313G>T p.M771I | Missense Mutation (SNP) | VAF 265/534 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1278627588; called by muse, mutect2, varscan2
- PRKD2 | c.2301G>T p.M767I | Missense Mutation (SNP) | VAF 495/660 reads (75%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV52186419; called by muse, mutect2, varscan2
- PRRG3 | c.494G>T p.G165V | Missense Mutation (SNP) | VAF 206/664 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV104427608, COSV64850625, COSV64850742; called by muse, varscan2
- PRSS56 | c.340G>A p.G114R | Missense Mutation (SNP) | VAF 192/572 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.561); catalogued as rs894954030; called by muse, mutect2, varscan2
- PRUNE2 | c.1148C>A p.S383Y | Missense Mutation (SNP) | VAF 146/451 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65038468; called by muse, mutect2, varscan2
- PTGIS | c.481G>T p.E161* | Nonsense Mutation (SNP) | VAF 144/421 reads (34%) | catalogued as COSV54837117, COSV54840735; called by muse, mutect2, varscan2
- RALGPS1 | c.548A>G p.N183S | Missense Mutation (SNP) | VAF 222/328 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV52230370; called by muse, mutect2, varscan2
- RBBP6 | c.4022G>C p.S1341T | Missense Mutation (SNP) | VAF 89/439 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs1340718526; called by muse, mutect2, varscan2
- REG1A | c.390C>A p.S130R | Missense Mutation (SNP) | VAF 247/358 reads (69%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.644); catalogued as rs748244874; called by muse, mutect2, varscan2
- REG1B | c.383C>A p.S128Y | Missense Mutation (SNP) | VAF 130/212 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV100521481; called by muse, mutect2, varscan2
- RFPL2 | c.1126G>T p.E376* | Nonsense Mutation (SNP) | VAF 124/190 reads (65%) | catalogued as COSV50709083; called by muse, mutect2, varscan2
- RFPL3 | c.943G>T p.E315* (on ENST00000249007 / NM_001098535.1; = p.E286* on NM_006604.2) | Nonsense Mutation (SNP) | VAF 22/330 reads (7%) | catalogued as COSV50749989; called by muse, mutect2
- RGPD4 | c.3071A>T p.D1024V | Missense Mutation (SNP) | VAF 193/537 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as rs1178834144; called by muse, mutect2, varscan2
- RHBDF2 | c.1861G>T p.G621C | Missense Mutation (SNP) | VAF 118/375 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99166284; called by muse, mutect2, varscan2
- ROBO2 | c.3829G>A p.A1277T | Missense Mutation (SNP) | VAF 246/247 reads (100%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV59942113; called by muse, mutect2, varscan2
- RUVBL2 | c.475G>T p.G159C | Missense Mutation (SNP) | VAF 256/344 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99668898; called by muse, mutect2
- SCAF11 | c.2894G>T p.R965L | Missense Mutation (SNP) | VAF 247/553 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101014263; called by muse, mutect2, varscan2
- SCART1 | c.1756G>T p.D586Y | Missense Mutation (SNP) | VAF 440/668 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775536404; called by muse, mutect2, varscan2
- SDK2 | c.5796C>A p.F1932L | Missense Mutation (SNP) | VAF 228/369 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV66189478; called by muse, mutect2, varscan2
- SERHL2 | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 172/284 reads (61%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs757388028; called by muse, mutect2
- SFXN2 | c.653G>T p.R218L | Missense Mutation (SNP) | VAF 93/186 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.34); catalogued as COSV64012489; called by muse, mutect2, varscan2
- SHC3 | c.1626G>T p.K542N | Missense Mutation (SNP) | VAF 104/321 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65436898; called by muse, mutect2, varscan2
- SLC10A3 | c.217G>A p.V73M | Missense Mutation (SNP) | VAF 196/696 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.736); catalogued as rs782728908; called by muse, mutect2, varscan2
- SLC19A3 | c.425A>G p.Y142C | Missense Mutation (SNP) | VAF 300/440 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752695150; called by muse, mutect2, varscan2
- SLC30A3 | c.473G>T p.G158V | Missense Mutation (SNP) | VAF 269/414 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1336385311; called by muse, mutect2, varscan2
- SLC38A4 | c.215C>A p.P72H | Missense Mutation (SNP) | VAF 242/492 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as rs778035487, COSV99873014; called by mutect2, varscan2
- STARD8 | c.1337C>A p.A446D | Missense Mutation (SNP) | VAF 428/900 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.184); catalogued as COSV52930739; called by muse, mutect2, varscan2
- SYK | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 196/587 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs748600980, COSV65328960; called by muse, mutect2, varscan2
- TECTA | c.188G>T p.R63L | Missense Mutation (SNP) | VAF 72/261 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs757192942; called by mutect2, varscan2
- TEP1 | c.1166G>T p.R389I | Missense Mutation (SNP) | VAF 240/241 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV53000237; called by muse, mutect2, varscan2
- TFAP2D | c.17C>A p.P6Q | Missense Mutation (SNP) | VAF 188/332 reads (57%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.993); catalogued as rs866860773; called by muse, mutect2, varscan2
- TGIF2LX | c.246G>T p.E82D | Missense Mutation (SNP) | VAF 44/398 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.785); catalogued as COSV52214599; called by mutect2, varscan2
- THBS2 | c.380C>T p.T127I | Missense Mutation (SNP) | VAF 156/491 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs376392032; called by muse, mutect2, varscan2
- TKTL1 | c.795G>T p.E265D | Missense Mutation (SNP) | VAF 138/682 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.033); catalogued as COSV99474088; called by muse, mutect2, varscan2
- TLR7 | c.1618C>A p.P540T | Missense Mutation (SNP) | VAF 317/700 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as rs367693931; called by muse, mutect2, varscan2
- TNRC18 | c.3434G>C p.R1145P | Missense Mutation (SNP) | VAF 398/725 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV68164208; called by muse, mutect2, varscan2
- TRIM10 | c.745G>T p.E249* | Nonsense Mutation (SNP) | VAF 259/404 reads (64%) | catalogued as COSV64994407, COSV64994494; called by muse, mutect2, varscan2
- TRIM27 | c.1304G>T p.R435L | Missense Mutation (SNP) | VAF 433/634 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV65873729; called by muse, mutect2, varscan2
- TRIM66 | c.164G>A p.C55Y | Missense Mutation (SNP) | VAF 287/287 reads (100%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.229); catalogued as rs964481289; called by muse, mutect2, varscan2
- TROAP | c.119T>A p.V40E | Missense Mutation (SNP) | VAF 292/577 reads (51%) | SIFT tolerated (0.52); PolyPhen benign (0.014); catalogued as COSV99226879; called by muse, mutect2, varscan2
- TTN | c.26546C>T p.S8849L (on ENST00000591111; = p.S7922L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 257/407 reads (63%) | PolyPhen possibly damaging (0.683); catalogued as rs773637100, COSV60246912; called by muse, mutect2, varscan2
- TUBB8B | c.659C>A p.P220H | Missense Mutation (SNP) | VAF 119/618 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1243476480; called by muse, varscan2
- TUBGCP4 | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as rs1345902565; called by muse, varscan2
- USP39 | c.1423A>G p.I475V | Missense Mutation (SNP) | VAF 138/198 reads (70%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as rs1350251931; called by muse, mutect2, varscan2
- VPS39 | c.72G>T p.W24C | Missense Mutation (SNP) | VAF 125/382 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.969); catalogued as rs1020329181; called by muse, mutect2, varscan2
- ZNF317 | c.1075del p.E359Rfs*51 | Frame Shift Del (DEL) | VAF 425/597 reads (71%) | catalogued as COSV56109326; called by mutect2, pindel, varscan2
- ZNF382 | c.863G>T p.R288I | Missense Mutation (SNP) | VAF 361/504 reads (72%) | SIFT deleterious (0); PolyPhen benign (0.286); catalogued as COSV53088197, COSV53091934; called by muse, mutect2, varscan2
- ZNF568 | c.737G>T p.G246V | Missense Mutation (SNP) | VAF 94/436 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV61742116; called by muse, mutect2, varscan2
- ZNF595 | c.129G>A p.L43= | Splice Region (SNP) | VAF 50/112 reads (45%) | catalogued as rs779696861, COSV59549338, COSV59549720; called by mutect2, varscan2
- ZNF707 | c.685G>T p.E229* | Nonsense Mutation (SNP) | VAF 341/1577 reads (22%) | catalogued as rs929816453, COSV100690678; called by muse, mutect2, varscan2
- ZNF804A | c.1069G>A p.G357R | Missense Mutation (SNP) | VAF 151/260 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV100165637; called by muse, mutect2, varscan2
- ZNF804A | c.1070G>T p.G357V | Missense Mutation (SNP) | VAF 147/248 reads (59%) | SIFT deleterious (0.05); PolyPhen benign (0.261); catalogued as COSV56439293; called by mutect2, varscan2
- ZNF98 | c.1090del p.H364Tfs*91 | Frame Shift Del (DEL) | VAF 273/428 reads (64%) | catalogued as COSV63339629; called by mutect2, pindel, varscan2
- ZSWIM2 | c.1173C>A p.N391K | Missense Mutation (SNP) | VAF 243/375 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs571618049; called by mutect2, varscan2
- ABAT | c.155G>C p.G52A | Missense Mutation (SNP) | VAF 184/185 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ABCA1 | c.4447G>A p.G1483R | Missense Mutation (SNP) | VAF 173/269 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCA2 | c.643G>T p.V215L (on ENST00000614293; = p.V185L on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 93/292 reads (32%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- ABCC10 | c.3317A>T p.H1106L (on ENST00000372530 / NM_001198934.2; = p.H1078L on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 321/434 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- AC006059.2 | c.536C>A p.T179N | Missense Mutation (SNP) | VAF 506/507 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- AC100868.1 | c.1677G>T p.L559F | Missense Mutation (SNP) | VAF 204/705 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- AC136428.1 | c.107C>A p.S36Y | Missense Mutation (SNP) | VAF 116/446 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.955); called by muse, varscan2
- ADAMTS20 | c.1686G>A p.W562* | Nonsense Mutation (SNP) | VAF 227/526 reads (43%) | called by muse, mutect2, varscan2
- ADCY8 | c.3376del p.V1126Lfs*15 | Frame Shift Del (DEL) | VAF 169/926 reads (18%) | called by pindel, varscan2
- ADD2 | c.214C>A p.Q72K | Missense Mutation (SNP) | VAF 196/336 reads (58%) | SIFT tolerated (0.05); PolyPhen benign (0.005); called by muse, varscan2
- ADGRG4 | c.9164G>T p.G3055V | Missense Mutation (SNP) | VAF 257/407 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- ADGRV1 | c.12903G>T p.W4301C | Missense Mutation (SNP) | VAF 243/244 reads (100%) | SIFT tolerated (0.44); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ADPRS | c.613G>T p.E205* | Nonsense Mutation (SNP) | VAF 314/495 reads (63%) | called by muse, mutect2, varscan2
- AFAP1 | c.860G>T p.G287V | Missense Mutation (SNP) | VAF 58/218 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- AGAP4 | c.551G>C p.G184A | Missense Mutation (SNP) | VAF 202/230 reads (88%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- AHI1 | c.3262T>A p.W1088R | Missense Mutation (SNP) | VAF 115/387 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AJAP1 | c.809G>C p.R270T | Missense Mutation (SNP) | VAF 126/452 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, varscan2
- AK9 | c.2200G>T p.E734* | Nonsense Mutation (SNP) | VAF 180/263 reads (68%) | called by muse, mutect2, varscan2
- AMER1 | c.2453G>T p.G818V | Missense Mutation (SNP) | VAF 363/718 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ANK2 | c.11405G>T p.S3802I | Missense Mutation (SNP) | VAF 310/310 reads (100%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANKRD34B | c.564A>C p.E188D | Missense Mutation (SNP) | VAF 150/268 reads (56%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANO2 | c.1906T>A p.F636I (on ENST00000356134 / NM_001278597.3; = p.F640I on NM_001278596.3) | Missense Mutation (SNP) | VAF 209/409 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- ANO3 | c.2719T>C p.W907R | Missense Mutation (SNP) | VAF 279/280 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APBA2 | c.189C>A p.C63* | Nonsense Mutation (SNP) | VAF 491/711 reads (69%) | called by muse, mutect2, varscan2
- APOB | c.9755C>G p.T3252S | Missense Mutation (SNP) | VAF 125/437 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- AQR | c.1759G>C p.V587L | Missense Mutation (SNP) | VAF 105/321 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ARAP3 | c.2369G>T p.S790I | Missense Mutation (SNP) | VAF 271/273 reads (99%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARHGAP20 | c.1120G>C p.D374H | Missense Mutation (SNP) | VAF 90/301 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARL13A | c.188A>T p.D63V | Missense Mutation (SNP) | VAF 104/323 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- ARMC10 | c.1029C>G p.I343M | Missense Mutation (SNP) | VAF 109/279 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.145); called by muse, mutect2
- ARMC2 | c.886C>T p.L296F | Missense Mutation (SNP) | VAF 112/369 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARPP21 | c.445T>A p.L149I | Missense Mutation (SNP) | VAF 297/297 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ASCC3 | c.3934G>C p.A1312P | Missense Mutation (SNP) | VAF 100/366 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ASXL3 | c.1447C>G p.L483V | Missense Mutation (SNP) | VAF 109/488 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ATL3 | c.326G>A p.R109K | Missense Mutation (SNP) | VAF 120/447 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- ATP2B3 | c.3642C>A p.H1214Q | Missense Mutation (SNP) | VAF 433/579 reads (75%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- ATP7A | c.300G>T p.W100C | Missense Mutation (SNP) | VAF 121/365 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ATP7A | c.4429G>A p.V1477I | Missense Mutation (SNP) | VAF 194/603 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ATRX | c.3059C>A p.P1020H | Missense Mutation (SNP) | VAF 100/342 reads (29%) | SIFT tolerated, low confidence (0.33); PolyPhen possibly damaging (0.781); called by mutect2, varscan2
- AVIL | c.1619A>G p.N540S | Missense Mutation (SNP) | VAF 294/539 reads (55%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- BACH2 | c.2497G>T p.D833Y | Missense Mutation (SNP) | VAF 194/295 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- BARX2 | c.602C>G p.T201R | Missense Mutation (SNP) | VAF 174/259 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- BBOX1 | c.580T>A p.Y194N | Missense Mutation (SNP) | VAF 200/201 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BCAS1 | c.557C>T p.S186F | Missense Mutation (SNP) | VAF 128/467 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- BCL2L12 | c.866G>T p.R289L | Missense Mutation (SNP) | VAF 169/696 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- BCORL1 | c.3987G>T p.R1329S | Missense Mutation (SNP) | VAF 386/589 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BNC1 | c.1675C>A p.H559N | Missense Mutation (SNP) | VAF 148/419 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- BOD1L2 | c.31G>T p.G11C | Missense Mutation (SNP) | VAF 161/701 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- BRD1 | c.832G>T p.G278C | Missense Mutation (SNP) | VAF 180/534 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BTN3A1 | c.1489G>T p.V497F | Missense Mutation (SNP) | VAF 78/252 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- BX276092.9 | c.1485G>T p.Q495H | Missense Mutation (SNP) | VAF 219/334 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- C1QL3 | c.438C>G p.D146E | Missense Mutation (SNP) | VAF 281/406 reads (69%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C2orf81 | c.1048G>T p.D350Y | Missense Mutation (SNP) | VAF 155/509 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- C3 | c.4915G>T p.D1639Y | Missense Mutation (SNP) | VAF 275/276 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C8B | c.1570A>T p.I524F | Missense Mutation (SNP) | VAF 49/162 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- CATSPERZ | c.553T>C p.Y185H | Missense Mutation (SNP) | VAF 118/368 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- CBARP | c.855G>T p.K285N (on ENST00000382477; = p.K265N on NM_152769.3) | Missense Mutation (SNP) | VAF 457/457 reads (100%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC22 | c.605G>A p.R202K | Missense Mutation (SNP) | VAF 465/928 reads (50%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- CCDC80 | c.2164A>G p.R722G | Missense Mutation (SNP) | VAF 110/241 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- CD300LG | c.153C>A p.C51* | Nonsense Mutation (SNP) | VAF 114/385 reads (30%) | called by muse, mutect2, varscan2
- CDH11 | c.1672G>T p.G558* | Nonsense Mutation (SNP) | VAF 252/399 reads (63%) | called by muse, mutect2, varscan2
- CDH12 | c.2369del p.P790Lfs*55 | Frame Shift Del (DEL) | VAF 237/509 reads (47%) | called by mutect2, pindel, varscan2
- CDH6 | c.819C>A p.Y273* | Nonsense Mutation (SNP) | VAF 160/434 reads (37%) | called by muse, mutect2, varscan2
- CDH7 | c.1556T>C p.F519S | Missense Mutation (SNP) | VAF 314/443 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDH8 | c.1847C>A p.P616Q | Missense Mutation (SNP) | VAF 285/422 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- CDH8 | c.917G>T p.G306V | Missense Mutation (SNP) | VAF 258/408 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CEACAM20 | c.1571A>G p.E524G | Missense Mutation (SNP) | VAF 115/505 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CEACAM21 | c.334G>T p.V112F | Missense Mutation (SNP) | VAF 196/731 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CEP126 | c.1396C>G p.P466A | Missense Mutation (SNP) | VAF 134/415 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- CEP55 | c.31A>T p.K11* | Nonsense Mutation (SNP) | VAF 138/138 reads (100%) | called by muse, mutect2, varscan2
- CHCHD4 | c.240G>T p.E80D (on ENST00000396914 / NM_001098502.2; = p.E93D on NM_144636.3) | Missense Mutation (SNP) | VAF 446/453 reads (98%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- CHD7 | c.7612G>T p.D2538Y | Missense Mutation (SNP) | VAF 146/278 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- CHRFAM7A | c.946G>A p.V316M | Missense Mutation (SNP) | VAF 289/460 reads (63%) | SIFT tolerated (0.29); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CHST4 | c.129G>A p.M43I | Missense Mutation (SNP) | VAF 157/560 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CNTN2 | c.2141C>A p.P714H | Missense Mutation (SNP) | VAF 356/356 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CNTNAP4 | c.2842G>A p.A948T | Missense Mutation (SNP) | VAF 83/323 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- COL12A1 | c.1798G>T p.E600* | Nonsense Mutation (SNP) | VAF 133/419 reads (32%) | called by muse, mutect2, varscan2
- COL14A1 | c.4591_4592delinsA p.L1531Ifs*41 | Frame Shift Del (DEL) | VAF 369/1055 reads (35%) | called by pindel, varscan2*
- COL19A1 | c.3385C>G p.L1129V | Missense Mutation (SNP) | VAF 82/270 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- COL5A2 | c.1051G>T p.G351C | Missense Mutation (SNP) | VAF 202/312 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COL6A3 | c.4254G>T p.K1418N | Missense Mutation (SNP) | VAF 153/450 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL7A1 | c.7739G>T p.R2580L | Missense Mutation (SNP) | VAF 176/176 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- COQ2 | c.1177G>T p.V393F | Missense Mutation (SNP) | VAF 192/193 reads (99%) | SIFT tolerated (0.11); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- CRB2 | c.3058G>T p.G1020C | Missense Mutation (SNP) | VAF 336/503 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSF2RB | c.915C>A p.H305Q | Missense Mutation (SNP) | VAF 462/666 reads (69%) | SIFT tolerated (0.14); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- CSH1 | c.124C>T p.Q42* | Nonsense Mutation (SNP) | VAF 141/180 reads (78%) | called by muse, mutect2, varscan2
- CSMD2 | c.2792C>A p.S931Y | Missense Mutation (SNP) | VAF 122/376 reads (32%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.934); called by muse, mutect2
- CSMD3 | c.3188G>C p.C1063S (on ENST00000297405 / NM_001363185.1; = p.C959S on NM_052900.3) | Missense Mutation (SNP) | VAF 309/405 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- CYP2C19 | c.1409C>A p.T470N | Missense Mutation (SNP) | VAF 240/240 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.134); called by mutect2, varscan2
- DAOA | c.449C>A p.T150N | Missense Mutation (SNP) | VAF 58/127 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.381); called by mutect2, varscan2
- DCAF4L2 | c.290C>A p.S97Y | Missense Mutation (SNP) | VAF 178/465 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- DCHS1 | c.9415G>T p.G3139C | Missense Mutation (SNP) | VAF 345/345 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- DDX3X | c.1534G>A p.V512I (on ENST00000399959; = p.V513I on NM_001356.5) | Missense Mutation (SNP) | VAF 181/363 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- DIP2A | c.3599G>T p.G1200V | Missense Mutation (SNP) | VAF 135/270 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH11 | c.5599G>T p.V1867L | Missense Mutation (SNP) | VAF 172/369 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- DNAH17 | c.9414G>T p.E3138D | Missense Mutation (SNP) | VAF 272/428 reads (64%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- DNAH5 | c.6269G>C p.R2090P | Missense Mutation (SNP) | VAF 80/486 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH8 | c.10568C>A p.P3523Q | Missense Mutation (SNP) | VAF 86/277 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- DNER | c.514A>T p.T172S | Missense Mutation (SNP) | VAF 106/328 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- DOP1B | c.1609A>T p.S537C | Missense Mutation (SNP) | VAF 27/250 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- DPYS | c.621G>T p.L207F | Missense Mutation (SNP) | VAF 227/396 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- DYNC2I1 | c.1982A>T p.H661L | Missense Mutation (SNP) | VAF 349/349 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- DYSF | c.2578C>A p.L860I | Missense Mutation (SNP) | VAF 236/360 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EBF3 | c.1620C>A p.S540R | Missense Mutation (SNP) | VAF 302/438 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- EBF3 | c.1037C>G p.T346S (on ENST00000355311 / NM_001375392.1; = p.T337S on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 160/248 reads (65%) | SIFT tolerated (0.08); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- ECM1 | c.620G>T p.G207V | Missense Mutation (SNP) | VAF 476/633 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EDN3 | c.227C>A p.P76H | Missense Mutation (SNP) | VAF 235/591 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ELP3 | c.493G>T p.V165L | Missense Mutation (SNP) | VAF 129/295 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- EMSY | c.815A>G p.N272S | Missense Mutation (SNP) | VAF 136/219 reads (62%) | SIFT tolerated (0.38); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ENOX2 | c.562C>A p.L188M (on ENST00000338144 / NM_001382520.1; = p.L159M on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 127/479 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- EPB41L3 | c.621G>T p.L207F | Missense Mutation (SNP) | VAF 223/305 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPS8L3 | c.149C>A p.A50D | Missense Mutation (SNP) | VAF 166/340 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- ERBB4 | c.1124+1del p.X375_splice | Splice Site (DEL) | VAF 96/202 reads (48%) | called by mutect2, pindel, varscan2
- EXOC2 | c.1773G>C p.L591F | Missense Mutation (SNP) | VAF 70/214 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- EXOC8 | c.125A>T p.Q42L | Missense Mutation (SNP) | VAF 616/616 reads (100%) | SIFT tolerated (1); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- EXTL3 | c.1924G>T p.G642* | Nonsense Mutation (SNP) | VAF 254/481 reads (53%) | called by muse, mutect2, varscan2
- EZHIP | c.698C>A p.P233H | Missense Mutation (SNP) | VAF 329/680 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- FAM117A | c.376T>A p.S126T | Missense Mutation (SNP) | VAF 71/265 reads (27%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- FAM135B | c.3768C>A p.N1256K | Missense Mutation (SNP) | VAF 77/548 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- FAM47A | c.1481A>C p.Q494P | Missense Mutation (SNP) | VAF 430/908 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.013); called by mutect2, varscan2
- FAM47A | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 253/536 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FAM83B | c.1366C>A p.L456I | Missense Mutation (SNP) | VAF 118/450 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- FAM83E | c.61del p.A21Pfs*19 | Frame Shift Del (DEL) | VAF 431/725 reads (59%) | called by mutect2, pindel, varscan2
- FANCM | c.4279G>T p.V1427F | Missense Mutation (SNP) | VAF 149/386 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- FBH1 | c.3074G>T p.R1025L (on ENST00000362091 / NM_178150.3; = p.R1076L on NM_032807.4) | Missense Mutation (SNP) | VAF 149/463 reads (32%) | SIFT tolerated (0.65); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FBXO42 | c.1600A>G p.T534A | Missense Mutation (SNP) | VAF 201/484 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- FCAR | c.825dup p.G276Rfs*18 | Frame Shift Ins (INS) | VAF 541/920 reads (59%) | called by mutect2, pindel, varscan2
- FGD1 | c.1489G>T p.E497* | Nonsense Mutation (SNP) | VAF 269/538 reads (50%) | called by muse, mutect2, varscan2
- FGF17 | c.5G>T p.G2V | Missense Mutation (SNP) | VAF 218/502 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FIGN | c.1703A>G p.H568R | Missense Mutation (SNP) | VAF 249/400 reads (62%) | SIFT tolerated (0.46); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- FLNA | c.1244dup p.V416Gfs*64 | Frame Shift Ins (INS) | VAF 130/453 reads (29%) | called by mutect2, pindel, varscan2
- FMN1 | c.613T>C p.S205P | Missense Mutation (SNP) | VAF 242/397 reads (61%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- FMR1 | c.1631G>T p.R544I | Missense Mutation (SNP) | VAF 180/474 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- FN3K | c.297A>T p.Q99H | Missense Mutation (SNP) | VAF 106/180 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FOXG1 | c.412G>C p.A138P | Missense Mutation (SNP) | VAF 209/740 reads (28%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- FREM3 | c.844G>T p.A282S | Missense Mutation (SNP) | VAF 334/334 reads (100%) | SIFT tolerated (0.68); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FSIP2 | c.15205C>A p.Q5069K | Missense Mutation (SNP) | VAF 147/219 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- GAB4 | c.977C>A p.A326D | Missense Mutation (SNP) | VAF 124/409 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- GABRA6 | c.503A>T p.H168L | Missense Mutation (SNP) | VAF 82/194 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABRD | c.122T>A p.L41H | Missense Mutation (SNP) | VAF 310/433 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GCSAML | c.140G>T p.S47I | Missense Mutation (SNP) | VAF 192/194 reads (99%) | SIFT tolerated (0.05); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- GJD4 | c.277A>T p.S93C | Missense Mutation (SNP) | VAF 299/748 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- GLMN | c.1099G>T p.G367C | Missense Mutation (SNP) | VAF 81/198 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GLOD5 | c.39G>T p.M13I | Missense Mutation (SNP) | VAF 299/595 reads (50%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- GLYATL1B | c.764T>A p.L255Q | Missense Mutation (SNP) | VAF 128/421 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPAA1 | c.605T>A p.V202D | Missense Mutation (SNP) | VAF 93/679 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- GPLD1 | c.1289A>T p.D430V | Missense Mutation (SNP) | VAF 136/429 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- GPR156 | c.499G>T p.G167W | Missense Mutation (SNP) | VAF 195/196 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPR34 | c.776G>T p.G259V | Missense Mutation (SNP) | VAF 238/543 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- GPRASP1 | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 146/492 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- GRID2 | c.1633G>A p.V545M | Missense Mutation (SNP) | VAF 284/285 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRID2IP | c.763C>A p.P255T | Missense Mutation (SNP) | VAF 298/588 reads (51%) | SIFT tolerated (0.39); PolyPhen benign (0.107); called by muse, varscan2
- GRK1 | c.851A>T p.E284V | Missense Mutation (SNP) | VAF 96/239 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- GTF2A2 | c.153G>C p.R51S | Missense Mutation (SNP) | VAF 149/250 reads (60%) | SIFT tolerated (0.13); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- GTF3C1 | c.5338_5355del p.F1780_Q1785del | In Frame Del (DEL) | VAF 84/430 reads (20%) | called by mutect2, pindel, varscan2
- HAL | c.376C>G p.L126V | Missense Mutation (SNP) | VAF 248/491 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- HAUS7 | c.577G>C p.D193H | Missense Mutation (SNP) | VAF 183/859 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- HEATR5B | c.1061G>T p.R354I | Missense Mutation (SNP) | VAF 89/306 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- HFM1 | c.3980T>A p.V1327D | Missense Mutation (SNP) | VAF 59/160 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- HNRNPCL1 | c.613G>C p.E205Q | Missense Mutation (SNP) | VAF 129/698 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- HNRNPH2 | c.947G>T p.R316I | Missense Mutation (SNP) | VAF 202/594 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- HRG | c.212T>C p.L71S | Missense Mutation (SNP) | VAF 237/237 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HSD17B12 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 96/212 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- HTR2A | c.573G>T p.K191N | Missense Mutation (SNP) | VAF 128/241 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by mutect2, varscan2
- HYDIN | c.14149T>A p.W4717R | Missense Mutation (SNP) | VAF 55/263 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- IGHV3-16 | c.89T>A p.L30* | Nonsense Mutation (SNP) | VAF 342/354 reads (97%) | called by muse, mutect2, varscan2
- IL13RA1 | c.88G>C p.E30Q | Missense Mutation (SNP) | VAF 86/265 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- IL4R | c.2341G>T p.A781S | Missense Mutation (SNP) | VAF 131/593 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- INPP5B | c.1201del p.E401Sfs*19 (on ENST00000373023; = p.E321Sfs*19 on NM_005540.3 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 76/250 reads (30%) | called by mutect2, pindel*, varscan2
- INTS2 | c.1723G>A p.D575N | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- IRF2BP2 | c.506C>G p.P169R | Missense Mutation (SNP) | VAF 157/504 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- ISL1 | c.974G>T p.G325V | Missense Mutation (SNP) | VAF 131/382 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.382); called by mutect2, varscan2
- ITGA4 | c.1156G>T p.V386F | Missense Mutation (SNP) | VAF 146/236 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- ITIH5 | c.1927A>T p.M643L | Missense Mutation (SNP) | VAF 133/438 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ITIH5 | c.883A>T p.N295Y | Missense Mutation (SNP) | VAF 103/317 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITPR2 | c.530T>C p.V177A | Missense Mutation (SNP) | VAF 61/278 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- KBTBD6 | c.1016G>T p.G339V | Missense Mutation (SNP) | VAF 98/250 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- KCNC2 | c.1262T>A p.F421Y | Missense Mutation (SNP) | VAF 281/581 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNN3 | c.1842A>T p.K614N (on ENST00000618040 / NM_001204087.1; = p.K599N on NM_002249.6) | Missense Mutation (SNP) | VAF 254/363 reads (70%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- KCTD11 | c.421C>T p.H141Y (on ENST00000333751 / NM_001363642.1; = p.H102Y on NM_001002914.2) | Missense Mutation (SNP) | VAF 577/578 reads (100%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- KDR | c.2439G>T p.L813F | Missense Mutation (SNP) | VAF 338/338 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- KERA | c.478G>T p.G160W | Missense Mutation (SNP) | VAF 293/566 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF17 | c.207C>A p.N69K | Missense Mutation (SNP) | VAF 216/340 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- KIRREL3 | c.385G>T p.A129S | Missense Mutation (SNP) | VAF 152/455 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KLHL31 | c.1442G>T p.R481L | Missense Mutation (SNP) | VAF 305/471 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KLK6 | c.639G>T p.W213C | Missense Mutation (SNP) | VAF 154/704 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KMT2B | c.2782G>A p.E928K | Missense Mutation (SNP) | VAF 143/693 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KRT2 | c.1298A>T p.H433L | Missense Mutation (SNP) | VAF 198/442 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- KRTAP20-1 | c.12C>A p.Y4* | Nonsense Mutation (SNP) | VAF 87/207 reads (42%) | called by muse, mutect2, varscan2
- KRTAP5-5 | c.571C>A p.P191T | Missense Mutation (SNP) | VAF 416/434 reads (96%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.308); called by muse, varscan2
- LAMA2 | c.7665C>A p.S2555R | Missense Mutation (SNP) | VAF 132/403 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LHX2 | c.811A>T p.T271S | Missense Mutation (SNP) | VAF 192/564 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- LILRB2 | c.1684T>G p.Y562D | Missense Mutation (SNP) | VAF 141/631 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- LPIN1 | c.1027G>T p.V343L | Missense Mutation (SNP) | VAF 113/381 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRP12 | c.1785G>T p.M595I | Missense Mutation (SNP) | VAF 205/362 reads (57%) | SIFT tolerated (0.5); PolyPhen benign (0); called by mutect2, varscan2
- LRP1B | c.11096G>T p.C3699F | Missense Mutation (SNP) | VAF 249/386 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC4B | c.181T>C p.C61R | Missense Mutation (SNP) | VAF 205/899 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC7 | c.42C>A p.Y14* | Nonsense Mutation (SNP) | VAF 130/265 reads (49%) | called by muse, mutect2, varscan2
- LRRC9 | c.3273C>A p.N1091K | Missense Mutation (SNP) | VAF 107/248 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- LRRK2 | c.2367G>T p.L789F | Missense Mutation (SNP) | VAF 152/602 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MACF1 | c.21557G>C p.R7186P (on ENST00000372915; = p.R5231P on NM_012090.5) | Missense Mutation (SNP) | VAF 139/244 reads (57%) | called by muse, mutect2, varscan2
- MAGEA12 | c.907C>A p.P303T | Missense Mutation (SNP) | VAF 85/290 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.055); called by muse, mutect2
- MAP3K2 | c.1522C>T p.L508F | Missense Mutation (SNP) | VAF 146/446 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- MBD3L3 | c.471G>T p.M157I | Missense Mutation (SNP) | VAF 303/1006 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MBD5 | c.2504C>A p.T835K | Missense Mutation (SNP) | VAF 105/416 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- MED12 | c.4794G>T p.M1598I | Missense Mutation (SNP) | VAF 261/600 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- MEI4 | c.627G>T p.W209C | Missense Mutation (SNP) | VAF 93/327 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- MPHOSPH8 | c.967G>C p.D323H | Missense Mutation (SNP) | VAF 133/272 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- MRC1 | c.1432T>C p.C478R | Missense Mutation (SNP) | VAF 279/430 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MRC1 | c.2719G>T p.G907W | Missense Mutation (SNP) | VAF 78/288 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MROH2A | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 53/212 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- MROH5 | c.1866G>T p.L622F | Missense Mutation (SNP) | VAF 95/658 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MRPL28 | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 96/236 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MS4A18 | c.394C>A p.Q132K | Missense Mutation (SNP) | VAF 126/379 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- MS4A5 | c.46C>A p.P16T | Missense Mutation (SNP) | VAF 130/381 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- MTMR8 | c.315A>T p.L105F | Missense Mutation (SNP) | VAF 66/346 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- MUC12 | c.13292C>A p.P4431H (on ENST00000379442; = p.P4288H on NM_001164462.1) | Missense Mutation (SNP) | VAF 175/404 reads (43%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- MXRA5 | c.444C>G p.N148K | Missense Mutation (SNP) | VAF 345/736 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MYCBP2 | c.3111_3114del p.A1038Hfs*10 (on ENST00000357337; = p.A1076Hfs*10 on NM_015057.5) | Frame Shift Del (DEL) | VAF 73/187 reads (39%) | called by mutect2, pindel, varscan2
- MYH13 | c.3194T>A p.M1065K | Missense Mutation (SNP) | VAF 260/260 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MYH13 | c.2347G>T p.E783* | Nonsense Mutation (SNP) | VAF 256/256 reads (100%) | called by muse, mutect2, varscan2
- MYH14 | c.2607G>T p.E869D | Missense Mutation (SNP) | VAF 92/561 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYH14 | c.2608G>T p.V870L | Missense Mutation (SNP) | VAF 91/560 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYH7 | c.5291T>G p.M1764R | Missense Mutation (SNP) | VAF 186/409 reads (45%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- MYH7 | c.2042C>T p.P681L | Missense Mutation (SNP) | VAF 150/303 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH7B | c.2600G>T p.R867L | Missense Mutation (SNP) | VAF 242/373 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MYO1B | c.1140G>T p.K380N | Missense Mutation (SNP) | VAF 85/266 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- MYO7B | c.2603G>C p.G868A | Missense Mutation (SNP) | VAF 157/447 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- NCAN | c.1883C>G p.P628R | Missense Mutation (SNP) | VAF 399/400 reads (100%) | SIFT tolerated (0.61); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- NCKAP5 | c.345G>T p.M115I | Missense Mutation (SNP) | VAF 61/254 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- NEK1 | c.1444G>T p.G482* | Nonsense Mutation (SNP) | VAF 155/155 reads (100%) | called by muse, mutect2, varscan2
- NEURL1 | c.859C>A p.P287T | Missense Mutation (SNP) | VAF 247/249 reads (99%) | SIFT deleterious (0.03); PolyPhen benign (0.335); called by muse, varscan2
- NFATC2 | c.1788G>T p.M596I | Missense Mutation (SNP) | VAF 326/473 reads (69%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NLRP12 | c.1719C>A p.S573R | Missense Mutation (SNP) | VAF 120/500 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- NLRP5 | c.334C>A p.L112I | Missense Mutation (SNP) | VAF 173/609 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NOS1 | c.4045G>A p.G1349S | Missense Mutation (SNP) | VAF 292/566 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOS1 | c.555G>T p.Q185H | Missense Mutation (SNP) | VAF 275/574 reads (48%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- NOS1 | c.554A>T p.Q185L | Missense Mutation (SNP) | VAF 276/575 reads (48%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOTCH3 | c.1766A>T p.Q589L | Missense Mutation (SNP) | VAF 79/723 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- NOTCH4 | c.4573G>C p.V1525L | Missense Mutation (SNP) | VAF 113/389 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- NOVA2 | c.677C>A p.P226H | Missense Mutation (SNP) | VAF 187/736 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NOX1 | c.22C>A p.H8N | Missense Mutation (SNP) | VAF 144/473 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NPTX2 | c.851G>C p.W284S | Missense Mutation (SNP) | VAF 210/433 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- NR4A1 | c.1427C>T p.A476V | Missense Mutation (SNP) | VAF 141/632 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NSMF | c.1575C>G p.D525E (on ENST00000371475 / NM_001130969.3; = p.D523E on NM_015537.4) | Missense Mutation (SNP) | VAF 100/358 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NYX | c.853C>A p.L285M | Missense Mutation (SNP) | VAF 465/972 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OGFOD3 | c.659G>T p.R220L | Missense Mutation (SNP) | VAF 135/399 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- OR10Z1 | c.29G>T p.R10M | Missense Mutation (SNP) | VAF 284/284 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OR13D1 | c.163C>T p.L55F | Missense Mutation (SNP) | VAF 273/420 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- OR14C36 | c.734T>A p.V245E | Missense Mutation (SNP) | VAF 419/420 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- OR14J1 | c.889G>T p.A297S | Missense Mutation (SNP) | VAF 241/378 reads (64%) | SIFT tolerated (0.23); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- OR56A5 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 153/153 reads (100%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR5B12 | c.308T>A p.V103E | Missense Mutation (SNP) | VAF 305/446 reads (68%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- OR5D14 | c.323C>G p.T108S | Missense Mutation (SNP) | VAF 272/401 reads (68%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OR5K3 | c.85G>T p.V29L | Missense Mutation (SNP) | VAF 215/215 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR5M3 | c.283dup p.C95Lfs*25 | Frame Shift Ins (INS) | VAF 104/420 reads (25%) | called by mutect2, pindel, varscan2
- OR6B1 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 302/303 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR6C3 | c.241del p.A81Qfs*26 | Frame Shift Del (DEL) | VAF 298/727 reads (41%) | called by mutect2, pindel, varscan2
- OR6S1 | c.434G>T p.R145L | Missense Mutation (SNP) | VAF 270/270 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OR8G5 | c.-14-3C>A | Splice Region (SNP) | VAF 240/362 reads (66%) | called by muse, mutect2
- OR8K5 | c.12_13del p.H4Qfs*7 | Frame Shift Del (DEL) | VAF 124/272 reads (46%) | called by pindel, varscan2
- ORC6 | c.730G>T p.A244S | Missense Mutation (SNP) | VAF 86/280 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- OTOG | c.5938C>A p.R1980S | Missense Mutation (SNP) | VAF 313/313 reads (100%) | SIFT tolerated (0.82); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PASD1 | c.1192C>A p.Q398K | Missense Mutation (SNP) | VAF 142/448 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- PAX7 | c.199A>T p.I67F | Missense Mutation (SNP) | VAF 308/466 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PDE3A | c.2299C>G p.L767V | Missense Mutation (SNP) | VAF 226/499 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, varscan2
- PDE3A | c.2630del p.F877Sfs*10 | Frame Shift Del (DEL) | VAF 144/655 reads (22%) | called by mutect2, pindel, varscan2
- PDZK1 | c.838G>C p.A280P | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by mutect2, varscan2
- PEDS1-UBE2V1 | c.1004A>G p.Q335R | Missense Mutation (SNP) | VAF 109/341 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- PGR | c.2611T>A p.Y871N | Missense Mutation (SNP) | VAF 216/359 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PKHD1L1 | c.6107C>T p.S2036L | Missense Mutation (SNP) | VAF 248/444 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PKNOX2 | c.1034G>T p.R345L | Missense Mutation (SNP) | VAF 213/310 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- PLD5 | c.231C>A p.C77* (on ENST00000442594; = p.C15* on NM_001195811.1 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 319/326 reads (98%) | called by muse, mutect2, varscan2
- PLEKHA6 | c.3128G>T p.S1043I | Missense Mutation (SNP) | VAF 273/273 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); called by mutect2, varscan2
- PLEKHG3 | c.193T>A p.S65T | Missense Mutation (SNP) | VAF 368/372 reads (99%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- PLEKHG4B | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 425/738 reads (58%) | SIFT tolerated (0.36); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- PLK5 | c.821T>C p.V274A | Missense Mutation (SNP) | VAF 299/299 reads (100%) | SIFT tolerated (0.09); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PLPPR4 | c.824C>G p.S275C | Missense Mutation (SNP) | VAF 85/172 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- PLSCR4 | c.421A>G p.N141D | Missense Mutation (SNP) | VAF 160/163 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PLXNA1 | c.3484G>T p.E1162* | Nonsense Mutation (SNP) | VAF 243/243 reads (100%) | called by muse, mutect2, varscan2
- PNPLA5 | c.227G>C p.G76A | Missense Mutation (SNP) | VAF 112/338 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- POGZ | c.181G>T p.V61F | Missense Mutation (SNP) | VAF 356/483 reads (74%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- POLRMT | c.259G>T p.D87Y | Missense Mutation (SNP) | VAF 498/502 reads (99%) | SIFT deleterious (0.01); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- POTEA | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- POTEE | c.2137G>T p.G713C | Missense Mutation (SNP) | VAF 180/312 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPFIA2 | c.2056G>C p.A686P | Missense Mutation (SNP) | VAF 273/557 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PPIL3 | c.146T>C p.F49S | Missense Mutation (SNP) | VAF 160/239 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP1R32 | c.23G>T p.G8V | Missense Mutation (SNP) | VAF 292/464 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP4R3C | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 180/385 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- PRAG1 | c.3487G>T p.G1163W | Missense Mutation (SNP) | VAF 176/304 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.864); called by mutect2, varscan2
- PRICKLE3 | c.1717C>T p.H573Y | Missense Mutation (SNP) | VAF 189/818 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- PRKCG | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 209/807 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- PRKD2 | c.2511G>T p.W837C | Missense Mutation (SNP) | VAF 598/769 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PRRT4 | c.2630A>T p.Q877L | Missense Mutation (SNP) | VAF 280/280 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- PRRX2 | c.311A>T p.Q104L | Missense Mutation (SNP) | VAF 308/451 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by muse, varscan2
- PXK | c.193A>T p.S65C | Missense Mutation (SNP) | VAF 84/84 reads (100%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- QPCT | c.488del p.P163Hfs*4 | Frame Shift Del (DEL) | VAF 123/458 reads (27%) | called by mutect2, pindel, varscan2
- RAB12 | c.507G>T p.Q169H | Missense Mutation (SNP) | VAF 296/403 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- RABGAP1 | c.1148G>A p.G383E | Missense Mutation (SNP) | VAF 85/300 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- RALGAPA1 | c.106G>C p.E36Q | Missense Mutation (SNP) | VAF 168/836 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RBBP8NL | c.947A>T p.D316V | Missense Mutation (SNP) | VAF 163/476 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- RBMX2 | c.202G>T p.V68L | Missense Mutation (SNP) | VAF 100/374 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- RGS20 | c.622T>C p.C208R (on ENST00000297313 / NM_170587.4; = p.C61R on NM_003702.4) | Missense Mutation (SNP) | VAF 337/609 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- RIMBP2 | c.1000G>C p.V334L | Missense Mutation (SNP) | VAF 281/629 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- RNF145 | c.748C>G p.R250G (on ENST00000424310 / NM_001199383.2; = p.R278G on NM_144726.2) | Missense Mutation (SNP) | VAF 112/247 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- RNPC3 | c.631G>T p.D211Y | Missense Mutation (SNP) | VAF 86/177 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- RP1 | c.2788C>A p.L930I | Missense Mutation (SNP) | VAF 215/395 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- RTL9 | c.2213C>A p.S738Y | Missense Mutation (SNP) | VAF 190/596 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- RTL9 | c.4084G>T p.E1362* | Nonsense Mutation (SNP) | VAF 113/427 reads (26%) | called by muse, mutect2, varscan2
- RTTN | c.4987_4988insT p.A1663Vfs*10 | Frame Shift Ins (INS) | VAF 272/372 reads (73%) | called by mutect2, pindel*, varscan2
- RUNDC3B | c.1067A>T p.N356I | Missense Mutation (SNP) | VAF 263/561 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- S1PR1 | c.868C>A p.L290I | Missense Mutation (SNP) | VAF 130/263 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SAMD9 | c.2813G>T p.C938F | Missense Mutation (SNP) | VAF 236/495 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- SCD5 | c.405C>A p.H135Q | Missense Mutation (SNP) | VAF 195/195 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCYGR4 | c.26G>A p.C9Y | Missense Mutation (SNP) | VAF 89/405 reads (22%) | called by muse, mutect2, varscan2
- SEMA3D | c.1733G>A p.G578D | Missense Mutation (SNP) | VAF 180/358 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- SEZ6L | c.1196C>T p.P399L | Missense Mutation (SNP) | VAF 210/359 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SH2B2 | c.1963G>C p.E655Q | Missense Mutation (SNP) | VAF 165/569 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SH3RF3 | c.316G>T p.D106Y | Missense Mutation (SNP) | VAF 346/537 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- SHROOM4 | c.4207G>T p.E1403* | Nonsense Mutation (SNP) | VAF 197/426 reads (46%) | called by muse, mutect2, varscan2
- SIGLEC10 | c.919G>T p.G307W | Missense Mutation (SNP) | VAF 303/637 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SLC17A1 | c.1176del p.R393Dfs*12 | Frame Shift Del (DEL) | VAF 159/295 reads (54%) | called by mutect2, pindel, varscan2
- SLC17A5 | c.789G>C p.K263N | Missense Mutation (SNP) | VAF 178/262 reads (68%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- SLC1A4 | c.295G>T p.V99L | Missense Mutation (SNP) | VAF 132/498 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- SLC22A7 | c.658G>T p.E220* (on ENST00000372585 / NM_153320.2; = p.E218* on NM_006672.3) | Nonsense Mutation (SNP) | VAF 116/331 reads (35%) | called by muse, mutect2, varscan2
- SLC4A11 | c.1315G>A p.A439T | Missense Mutation (SNP) | VAF 217/217 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- SLC9A9 | c.1732G>A p.V578M | Missense Mutation (SNP) | VAF 176/176 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLCO5A1 | c.1993G>T p.A665S | Missense Mutation (SNP) | VAF 74/295 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- SMARCD2 | c.153_154insT p.G52Wfs*92 | Frame Shift Ins (INS) | VAF 268/609 reads (44%) | called by pindel, varscan2
- SMCHD1 | c.1578G>T p.L526F | Missense Mutation (SNP) | VAF 362/481 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SMOC1 | c.1188G>T p.K396N | Missense Mutation (SNP) | VAF 268/268 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SMOC2 | c.1289C>T p.P430L (on ENST00000356284 / NM_001166412.2; = p.P441L on NM_022138.3) | Missense Mutation (SNP) | VAF 148/270 reads (55%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- SNURF | c.106C>A p.Q36K | Missense Mutation (SNP) | VAF 109/353 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SPRYD4 | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 277/569 reads (49%) | called by muse, mutect2, varscan2
- ST6GAL2 | c.776C>A p.A259E | Missense Mutation (SNP) | VAF 217/603 reads (36%) | PolyPhen benign (0.334); called by muse, mutect2, varscan2
- STRN4 | c.1463G>T p.R488L | Missense Mutation (SNP) | VAF 306/422 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STYXL2 | c.2117C>T p.P706L | Missense Mutation (SNP) | VAF 551/551 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- SVEP1 | c.2303A>T p.Y768F | Missense Mutation (SNP) | VAF 122/403 reads (30%) | SIFT tolerated (0.74); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- SZT2 | c.1742G>T p.R581L | Missense Mutation (SNP) | VAF 105/303 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TAF4B | c.97G>A p.V33M | Missense Mutation (SNP) | VAF 498/650 reads (77%) | SIFT deleterious (0.01); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- TAF4B | c.2329G>C p.E777Q | Missense Mutation (SNP) | VAF 14/369 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- TAGAP | c.847G>T p.V283L | Missense Mutation (SNP) | VAF 79/276 reads (29%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBX20 | c.380G>T p.R127M | Missense Mutation (SNP) | VAF 152/292 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TBX4 | c.1162C>A p.P388T | Missense Mutation (SNP) | VAF 196/614 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- TDRD6 | c.536T>A p.L179Q | Missense Mutation (SNP) | VAF 186/540 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TEAD4 | c.732G>T p.K244N | Missense Mutation (SNP) | VAF 82/399 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- TENM1 | c.5321G>C p.R1774T | Missense Mutation (SNP) | VAF 196/647 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- TEX11 | c.440C>A p.A147D (on ENST00000344304; = p.A132D on NM_031276.3) | Missense Mutation (SNP) | VAF 266/532 reads (50%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.521); called by muse, mutect2
- TEX15 | c.2652T>G p.N884K (on ENST00000256246; = p.N1267K on NM_001350162.2) | Missense Mutation (SNP) | VAF 207/413 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- TEX36 | c.17G>C p.R6P | Missense Mutation (SNP) | VAF 258/405 reads (64%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- TGFB1 | c.305A>G p.D102G | Missense Mutation (SNP) | VAF 164/763 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- THBS2 | c.1295C>A p.T432N | Missense Mutation (SNP) | VAF 180/273 reads (66%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- THSD7A | c.391C>A p.Q131K | Missense Mutation (SNP) | VAF 249/517 reads (48%) | SIFT tolerated (0.74); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TIAM1 | c.4236G>T p.Q1412H | Missense Mutation (SNP) | VAF 153/296 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- TINAG | c.370G>T p.G124C | Missense Mutation (SNP) | VAF 181/284 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- TJP1 | c.5026T>G p.C1676G | Missense Mutation (SNP) | VAF 332/496 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM132C | c.134T>A p.L45Q | Missense Mutation (SNP) | VAF 229/477 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- TMEM185A | c.733C>A p.P245T | Missense Mutation (SNP) | VAF 120/525 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TMEM271 | c.1033G>T p.G345W | Missense Mutation (SNP) | VAF 370/572 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMPRSS15 | c.1321A>T p.I441F | Missense Mutation (SNP) | VAF 96/220 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- TNN | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 419/419 reads (100%) | SIFT tolerated (0.72); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- TOX2 | c.449T>A p.M150K (on ENST00000358131 / NM_001098798.2; = p.M99K on NM_032883.3) | Missense Mutation (SNP) | VAF 104/416 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.388); called by muse, mutect2
- TRANK1 | c.2233G>A p.G745R | Missense Mutation (SNP) | VAF 514/514 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TRAPPC3L | c.158C>A p.T53K | Missense Mutation (SNP) | VAF 144/410 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- TRGV5 | c.239G>T p.G80V | Missense Mutation (SNP) | VAF 236/499 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRIM37 | c.1691A>T p.Y564F | Missense Mutation (SNP) | VAF 63/220 reads (29%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TRIM4 | c.1171G>T p.E391* | Nonsense Mutation (SNP) | VAF 290/562 reads (52%) | called by muse, mutect2, varscan2
- TRIM42 | c.1414A>G p.I472V | Missense Mutation (SNP) | VAF 270/270 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRPM2 | c.1711G>C p.D571H | Missense Mutation (SNP) | VAF 194/417 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- TSPYL2 | c.457_458insA p.G153Efs*9 | Frame Shift Ins (INS) | VAF 419/1020 reads (41%) | called by mutect2, pindel, varscan2
- TTC34 | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 145/706 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- TWIST1 | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 239/472 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- TXLNB | c.251G>T p.R84M | Missense Mutation (SNP) | VAF 357/519 reads (69%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBE2J2 | c.653G>T p.G218V | Missense Mutation (SNP) | VAF 236/905 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- UBXN10 | c.226A>G p.S76G | Missense Mutation (SNP) | VAF 136/430 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UGT1A9 | c.761G>T p.R254L | Missense Mutation (SNP) | VAF 252/398 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- UNC5C | c.1676T>C p.I559T | Missense Mutation (SNP) | VAF 170/170 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- UPRT | c.115G>T p.A39S | Missense Mutation (SNP) | VAF 216/694 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- UROC1 | c.1630G>T p.D544Y | Missense Mutation (SNP) | VAF 187/187 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UTF1 | c.706G>T p.D236Y | Missense Mutation (SNP) | VAF 256/383 reads (67%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- UTP14A | c.1384G>A p.V462I | Missense Mutation (SNP) | VAF 18/560 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- VAMP7 | c.392C>A p.A131D | Missense Mutation (SNP) | VAF 100/385 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WDCP | c.1778C>G p.P593R | Missense Mutation (SNP) | VAF 116/379 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- WDR44 | c.1079A>T p.K360M | Missense Mutation (SNP) | VAF 92/277 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- WDR81 | c.3998G>T p.R1333L (on ENST00000409644 / NM_001163809.2; = p.R282L on NM_152348.4) | Missense Mutation (SNP) | VAF 551/551 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- XIRP2 | c.937G>C p.V313L (on ENST00000628543; = p.V488L on NM_152381.6) | Missense Mutation (SNP) | VAF 115/366 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- YWHAG | c.408_433del p.E136Dfs*34 | Frame Shift Del (DEL) | VAF 258/620 reads (42%) | called by mutect2, pindel, varscan2
- ZBTB8A | c.1259T>C p.L420P | Missense Mutation (SNP) | VAF 216/356 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZCCHC18 | c.277C>A p.P93T | Missense Mutation (SNP) | VAF 148/505 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZEB1 | c.1127C>A p.T376N | Missense Mutation (SNP) | VAF 115/389 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF185 | c.2062C>A p.L688I | Missense Mutation (SNP) | VAF 94/269 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- ZNF189 | c.1466G>T p.C489F | Missense Mutation (SNP) | VAF 153/495 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF225 | c.1930A>G p.R644G | Missense Mutation (SNP) | VAF 100/346 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- ZNF260 | c.282G>T p.Q94H | Missense Mutation (SNP) | VAF 447/616 reads (73%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- ZNF329 | c.435G>C p.K145N | Missense Mutation (SNP) | VAF 337/337 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- ZNF746 | c.1316G>T p.G439V | Missense Mutation (SNP) | VAF 335/335 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- ZNF799 | c.1847C>T p.T616I | Missense Mutation (SNP) | VAF 193/629 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ZP4 | c.73G>T p.A25S | Missense Mutation (SNP) | VAF 356/357 reads (100%) | SIFT tolerated (0.72); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ZXDB | c.2033C>A p.S678Y | Missense Mutation (SNP) | VAF 81/479 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ABCA13 | c.6534A>T p.A2178= | Silent (SNP) | VAF 183/379 reads (48%) | called by muse, mutect2, varscan2
- ABCA2 | c.396C>T p.R132= (on ENST00000614293; = p.R102= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 145/461 reads (31%) | catalogued as rs373842222; called by muse, mutect2, varscan2
- ADAMTS15 | c.2229G>T p.V743= | Silent (SNP) | VAF 122/420 reads (29%) | called by muse, mutect2, varscan2
- ADAMTS5 | c.1482C>A p.T494= | Silent (SNP) | VAF 143/296 reads (48%) | called by mutect2, varscan2
- ADGB | c.4461C>T p.S1487= | Silent (SNP) | VAF 148/484 reads (31%) | called by muse, mutect2, varscan2
- ADGRB3 | c.2271A>G p.S757= | Silent (SNP) | VAF 62/229 reads (27%) | called by muse, mutect2, varscan2
- ADGRG4 | c.1920C>T p.S640= | Silent (SNP) | VAF 185/555 reads (33%) | called by muse, mutect2, varscan2
- AICDA | c.330C>T p.T110= | Silent (SNP) | VAF 285/591 reads (48%) | catalogued as rs1221122918, COSV104392632; called by muse, mutect2, varscan2
- ANKRD54 | c.171G>C p.A57= | Silent (SNP) | VAF 369/537 reads (69%) | called by muse, mutect2, varscan2
- APCDD1 | c.1212G>T p.V404= | Silent (SNP) | VAF 157/861 reads (18%) | catalogued as COSV62372572; called by muse, mutect2, varscan2
- APLNR | c.330C>T p.F110= | Silent (SNP) | VAF 137/404 reads (34%) | catalogued as rs769911270, COSV57241982; called by muse, mutect2, varscan2
- APOBR | c.930T>A p.A310= | Silent (SNP) | VAF 400/574 reads (70%) | called by muse, mutect2, varscan2
- ARAP1 | c.3087G>T p.S1029= (on ENST00000393609 / NM_001040118.2; = p.S784= on NM_015242.4) | Silent (SNP) | VAF 407/615 reads (66%) | catalogued as rs1239812666; called by muse, mutect2
- ARFGAP1 | c.159G>T p.G53= | Silent (SNP) | VAF 89/278 reads (32%) | called by muse, mutect2, varscan2
- ARSD | c.327C>T p.A109= | Silent (SNP) | VAF 259/536 reads (48%) | called by muse, mutect2, varscan2
- ASAP2 | c.213T>C p.N71= | Silent (SNP) | VAF 179/264 reads (68%) | catalogued as rs1217328936; called by muse, mutect2, varscan2
- ATAD5 | c.1575A>G p.T525= | Silent (SNP) | VAF 131/203 reads (65%) | catalogued as rs764289121; called by muse, mutect2, varscan2
- BACH2 | c.1209C>G p.S403= | Silent (SNP) | VAF 136/455 reads (30%) | called by muse, mutect2, varscan2
- BCL9 | c.1278G>T p.V426= | Silent (SNP) | VAF 470/654 reads (72%) | called by muse, mutect2, varscan2
- BCORL1 | c.78C>T p.N26= | Silent (SNP) | VAF 97/337 reads (29%) | called by muse, mutect2, varscan2
- BMP15 | c.798C>A p.T266= | Silent (SNP) | VAF 206/394 reads (52%) | called by muse, mutect2, varscan2
- BPGM | c.462G>T p.R154= | Silent (SNP) | VAF 317/318 reads (100%) | called by muse, mutect2, varscan2
- BPIFA3 | c.222A>T p.P74= | Silent (SNP) | VAF 111/422 reads (26%) | called by muse, mutect2, varscan2
- BTNL2 | c.978G>C p.L326= | Silent (SNP) | VAF 139/428 reads (32%) | called by muse, mutect2, varscan2
- CALN1 | c.642C>G p.L214= (on ENST00000329008 / NM_001017440.3; = p.L256= on NM_031468.4) | Silent (SNP) | VAF 139/319 reads (44%) | catalogued as COSV100209539; called by muse, mutect2, varscan2
- CARD11 | c.2757C>T p.V919= | Silent (SNP) | VAF 340/702 reads (48%) | catalogued as COSV62757109; called by muse, mutect2, varscan2
- CCER1 | c.168C>G p.P56= | Silent (SNP) | VAF 347/699 reads (50%) | catalogued as COSV62646951; called by muse, mutect2, varscan2
- CCL2 | c.180C>A p.P60= | Silent (SNP) | VAF 76/286 reads (27%) | catalogued as COSV56774169; called by muse, mutect2, varscan2
- CDCA3 | c.243C>T p.S81= | Silent (SNP) | VAF 156/328 reads (48%) | called by muse, varscan2
- CDH7 | c.516G>T p.V172= | Silent (SNP) | VAF 92/408 reads (23%) | catalogued as COSV100541755; called by muse, mutect2, varscan2
- CDH8 | c.10C>A p.R4= | Silent (SNP) | VAF 157/473 reads (33%) | catalogued as rs139797882, COSV54872322; ClinVar: likely benign; called by muse, mutect2, varscan2
- CDK2AP2 | c.177G>T p.V59= | Silent (SNP) | VAF 195/297 reads (66%) | catalogued as COSV100039363; called by muse, mutect2, varscan2
- CFAP45 | c.264A>C p.R88= | Silent (SNP) | VAF 287/288 reads (100%) | called by muse, mutect2, varscan2
- CHD6 | c.5451A>T p.P1817= | Silent (SNP) | VAF 271/401 reads (68%) | called by muse, mutect2, varscan2
- CHD6 | c.3417G>T p.V1139= | Silent (SNP) | VAF 137/455 reads (30%) | called by muse, mutect2, varscan2
- CMYA5 | c.384G>T p.V128= | Silent (SNP) | VAF 239/239 reads (100%) | called by muse, mutect2, varscan2
- CNGA2 | c.1396C>T p.L466= | Silent (SNP) | VAF 288/463 reads (62%) | catalogued as COSV61706246; called by muse, mutect2, varscan2
- CNTNAP5 | c.1482C>A p.P494= | Silent (SNP) | VAF 152/234 reads (65%) | catalogued as COSV70490746; called by muse, mutect2, varscan2
- CSH1 | c.123C>A p.L41= | Silent (SNP) | VAF 144/183 reads (79%) | called by muse, mutect2, varscan2
- CST4 | c.141C>A p.A47= | Silent (SNP) | VAF 189/190 reads (99%) | catalogued as COSV99463251; called by muse, mutect2, varscan2
- CST9L | c.348G>T p.L116= | Silent (SNP) | VAF 127/127 reads (100%) | catalogued as COSV65408380; called by muse, mutect2, varscan2
- CTNND2 | c.1449G>T p.A483= | Silent (SNP) | VAF 541/897 reads (60%) | called by muse, mutect2, varscan2
- CWC22 | c.285G>T p.G95= | Silent (SNP) | VAF 124/424 reads (29%) | called by muse, mutect2, varscan2
- CWC25 | c.1077A>G p.R359= | Silent (SNP) | VAF 179/542 reads (33%) | called by muse, mutect2, varscan2
- DDX19A | c.351A>T p.I117= | Silent (SNP) | VAF 109/356 reads (31%) | called by muse, mutect2, varscan2
- DHRS4L2 | c.279G>A p.A93= | Silent (SNP) | VAF 131/1182 reads (11%) | catalogued as rs542907863; called by muse, mutect2, varscan2
- DNAI3 | c.645C>A p.A215= | Silent (SNP) | VAF 105/224 reads (47%) | catalogued as rs931646748; called by muse, mutect2, varscan2
- DPY19L2 | c.825T>C p.L275= | Silent (SNP) | VAF 142/271 reads (52%) | called by muse, mutect2, varscan2
- EDEM2 | c.933C>G p.V311= | Silent (SNP) | VAF 203/339 reads (60%) | called by muse, mutect2, varscan2
- EFCAB8 | c.600G>T p.P200= | Silent (SNP) | VAF 224/367 reads (61%) | catalogued as COSV68700014; called by muse, mutect2, varscan2
- ELFN1 | c.2184G>A p.E728= | Silent (SNP) | VAF 212/892 reads (24%) | called by muse, mutect2, varscan2
- ELK1 | c.85C>A p.R29= | Silent (SNP) | VAF 395/820 reads (48%) | called by muse, mutect2, varscan2
- ENOX1 | c.168C>A p.G56= | Silent (SNP) | VAF 106/227 reads (47%) | called by muse, mutect2, varscan2
- EPB41L4B | c.2253C>A p.T751= | Silent (SNP) | VAF 278/426 reads (65%) | called by muse, mutect2, varscan2
- EPHB6 | c.1389T>A p.A463= | Silent (SNP) | VAF 481/481 reads (100%) | called by muse, mutect2, varscan2
- ESR1 | c.264G>T p.A88= | Silent (SNP) | VAF 376/562 reads (67%) | called by mutect2, varscan2
- FAM53C | c.327C>T p.P109= | Silent (SNP) | VAF 345/347 reads (99%) | called by muse, mutect2, varscan2
- FAM71C | c.624C>A p.A208= | Silent (SNP) | VAF 155/334 reads (46%) | called by muse, mutect2, varscan2
- FCN1 | c.519C>A p.A173= | Silent (SNP) | VAF 172/280 reads (61%) | catalogued as rs763319101; called by muse, mutect2, varscan2
- FOXL2NB | c.258G>T p.A86= | Silent (SNP) | VAF 377/380 reads (99%) | catalogued as COSV100374808; called by muse, mutect2, varscan2
- FOXN4 | c.1197C>A p.A399= | Silent (SNP) | VAF 379/756 reads (50%) | called by muse, mutect2, varscan2
- FOXO4 | c.1281G>C p.L427= | Silent (SNP) | VAF 381/851 reads (45%) | called by muse, mutect2, varscan2
- FSIP2 | c.8811C>A p.P2937= | Silent (SNP) | VAF 169/277 reads (61%) | called by muse, mutect2, varscan2
- FTHL17 | c.130C>A p.R44= | Silent (SNP) | VAF 374/731 reads (51%) | catalogued as COSV63266854; called by muse, mutect2, varscan2
- FUT1 | c.729G>T p.R243= | Silent (SNP) | VAF 166/676 reads (25%) | called by muse, mutect2, varscan2
- GABPA | c.708G>T p.R236= | Silent (SNP) | VAF 16/216 reads (7%) | catalogued as COSV100702358; called by muse, mutect2
- GAL3ST3 | c.816C>A p.A272= | Silent (SNP) | VAF 141/386 reads (37%) | called by muse, mutect2, varscan2
- GATAD2B | c.750A>T p.S250= | Silent (SNP) | VAF 125/623 reads (20%) | called by muse, mutect2, varscan2
- GJB3 | c.135G>C p.G45= | Silent (SNP) | VAF 310/477 reads (65%) | called by muse, mutect2, varscan2
- H1-2 | c.387G>A p.K129= | Silent (SNP) | VAF 208/323 reads (64%) | catalogued as rs766767455, COSV59190607; called by muse, mutect2, varscan2
- HOXA2 | c.1044C>G p.L348= | Silent (SNP) | VAF 412/678 reads (61%) | catalogued as COSV56065913; called by muse, mutect2, varscan2
- HOXB3 | c.282C>A p.A94= | Silent (SNP) | VAF 192/641 reads (30%) | called by muse, mutect2, varscan2
- IDH3G | c.840C>A p.V280= | Silent (SNP) | VAF 210/928 reads (23%) | called by muse, mutect2, varscan2
- IGKV1-8 | c.300T>A p.S100= | Silent (SNP) | VAF 240/310 reads (77%) | called by muse, mutect2, varscan2
- IL5RA | c.267C>A p.I89= | Silent (SNP) | VAF 301/302 reads (100%) | catalogued as COSV99842646; called by muse, mutect2, varscan2
- IQSEC2 | c.3486G>T p.L1162= | Silent (SNP) | VAF 276/590 reads (47%) | called by muse, varscan2
- ITGAE | c.2409C>A p.P803= | Silent (SNP) | VAF 365/365 reads (100%) | called by muse, mutect2, varscan2
- ITGAL | c.1191A>G p.P397= | Silent (SNP) | VAF 162/273 reads (59%) | called by muse, mutect2, varscan2
- ITIH5 | c.1926C>A p.A642= | Silent (SNP) | VAF 133/442 reads (30%) | called by muse, mutect2, varscan2
- JPH2 | c.531G>T p.P177= | Silent (SNP) | VAF 219/618 reads (35%) | called by muse, mutect2, varscan2
- KCNA6 | c.531C>G p.A177= | Silent (SNP) | VAF 237/519 reads (46%) | called by muse, mutect2, varscan2
- KCNB1 | c.1092C>T p.I364= | Silent (SNP) | VAF 134/568 reads (24%) | catalogued as COSV65569356; called by muse, mutect2, varscan2
- KCTD21 | c.216G>A p.E72= | Silent (SNP) | VAF 181/474 reads (38%) | called by muse, mutect2, varscan2
- KIAA1210 | c.1701C>A p.G567= | Silent (SNP) | VAF 187/643 reads (29%) | catalogued as COSV68175445; called by muse, mutect2, varscan2
- KIAA1549L | c.2805T>G p.P935= (on ENST00000321505; = p.P1232= on NM_012194.3) | Silent (SNP) | VAF 204/204 reads (100%) | called by muse, mutect2, varscan2
- KIAA2026 | c.4362A>G p.S1454= | Silent (SNP) | VAF 252/252 reads (100%) | called by muse, mutect2, varscan2
- KIR2DS4 | c.258C>A p.S86= | Silent (SNP) | VAF 397/533 reads (74%) | called by muse, mutect2, varscan2
- KIR3DL2 | c.288G>A p.R96= | Silent (SNP) | VAF 88/302 reads (29%) | called by muse, mutect2, varscan2
- KIR3DL3 | c.1083A>T p.A361= | Silent (SNP) | VAF 369/498 reads (74%) | called by muse, mutect2, varscan2
- KRT31 | c.393C>T p.I131= | Silent (SNP) | VAF 266/418 reads (64%) | catalogued as rs553792126, COSV52433404; called by muse, mutect2, varscan2
- KRTAP13-4 | c.327C>A p.S109= | Silent (SNP) | VAF 116/225 reads (52%) | called by muse, mutect2, varscan2
- KRTAP9-4 | c.312C>T p.T104= | Silent (SNP) | VAF 228/722 reads (32%) | called by muse, mutect2, varscan2
- L3MBTL1 | c.600G>T p.A200= (on ENST00000418998 / NM_001377303.1; = p.A110= on NM_015478.7) | Silent (SNP) | VAF 154/501 reads (31%) | catalogued as COSV100917327, COSV64232199; called by muse, mutect2, varscan2
- LAIR2 | c.81C>A p.P27= | Silent (SNP) | VAF 158/604 reads (26%) | called by muse, varscan2
- LAMB3 | c.3294G>C p.L1098= | Silent (SNP) | VAF 473/473 reads (100%) | called by muse, mutect2, varscan2
- LCP2 | c.786A>G p.P262= | Silent (SNP) | VAF 230/230 reads (100%) | called by muse, mutect2, varscan2
- LEPR | c.1797A>G p.P599= | Silent (SNP) | VAF 190/329 reads (58%) | called by muse, mutect2, varscan2
- LILRA4 | c.975C>G p.S325= | Silent (SNP) | VAF 344/480 reads (72%) | catalogued as COSV99392800; called by muse, mutect2, varscan2
- LOXL3 | c.840C>T p.S280= | Silent (SNP) | VAF 414/689 reads (60%) | called by muse, mutect2, varscan2
- MAGEA8 | c.327G>T p.R109= | Silent (SNP) | VAF 148/546 reads (27%) | called by muse, mutect2, varscan2
- MAGEL2 | c.114G>T p.R38= | Silent (SNP) | VAF 306/484 reads (63%) | called by muse, mutect2, varscan2
- MAGI2 | c.3285G>T p.P1095= | Silent (SNP) | VAF 377/755 reads (50%) | catalogued as COSV62704708; called by muse, mutect2, varscan2
- MBL2 | c.165C>G p.T55= | Silent (SNP) | VAF 207/207 reads (100%) | catalogued as COSV100906366; called by muse, mutect2, varscan2
- MC2R | c.306C>A p.A102= | Silent (SNP) | VAF 351/491 reads (71%) | called by muse, mutect2, varscan2
- MEGF11 | c.1215G>A p.L405= | Silent (SNP) | VAF 205/608 reads (34%) | called by muse, mutect2, varscan2
- MEGF8 | c.5550G>T p.G1850= (on ENST00000251268 / NM_001271938.2; = p.G1783= on NM_001410.3) | Silent (SNP) | VAF 206/751 reads (27%) | catalogued as COSV52100799; called by muse, mutect2, varscan2
- METTL23 | c.189G>A p.R63= | Silent (SNP) | VAF 124/397 reads (31%) | called by muse, mutect2, varscan2
- MFSD2B | c.103A>C p.R35= | Silent (SNP) | VAF 116/333 reads (35%) | called by muse, mutect2, varscan2
- MROH2A | c.1635C>T p.S545= | Silent (SNP) | VAF 256/390 reads (66%) | catalogued as rs1246711405; called by muse, mutect2, varscan2
- MROH2A | c.3063G>T p.L1021= | Silent (SNP) | VAF 109/303 reads (36%) | called by muse, mutect2, varscan2
- MRPL46 | c.220C>T p.L74= | Silent (SNP) | VAF 34/221 reads (15%) | called by muse, mutect2, varscan2
- MRPS35 | c.825T>C p.N275= | Silent (SNP) | VAF 237/482 reads (49%) | called by muse, mutect2, varscan2
- MYF6 | c.480G>T p.L160= | Silent (SNP) | VAF 178/385 reads (46%) | called by muse, varscan2
- MYO18B | c.5889C>A p.A1963= | Silent (SNP) | VAF 117/350 reads (33%) | called by muse, mutect2, varscan2
- MYT1L | c.1314C>T p.I438= | Silent (SNP) | VAF 180/525 reads (34%) | catalogued as rs1372627035, COSV67715216; called by muse, mutect2, varscan2
- NALCN | c.3987C>A p.V1329= | Silent (SNP) | VAF 107/231 reads (46%) | catalogued as COSV51925231; called by muse, mutect2, varscan2
- NAV3 | c.1476A>G p.T492= | Silent (SNP) | VAF 293/549 reads (53%) | catalogued as rs768411330; called by muse, mutect2, varscan2
- NEFL | c.780C>T p.D260= | Silent (SNP) | VAF 276/510 reads (54%) | catalogued as rs878854817; ClinVar: likely benign; called by muse, mutect2, varscan2
- NLGN4X | c.786G>T p.L262= | Silent (SNP) | VAF 259/566 reads (46%) | called by muse, mutect2, varscan2
- NME5 | c.24T>G p.P8= | Silent (SNP) | VAF 81/164 reads (49%) | called by muse, mutect2, varscan2
- NRIP1 | c.2910C>T p.T970= | Silent (SNP) | VAF 135/283 reads (48%) | called by muse, mutect2, varscan2
- OCA2 | c.441G>C p.L147= | Silent (SNP) | VAF 191/595 reads (32%) | called by muse, mutect2, varscan2
- OLFML2A | c.474C>G p.A158= | Silent (SNP) | VAF 77/221 reads (35%) | called by muse, mutect2, varscan2
- OR10G4 | c.321G>T p.G107= | Silent (SNP) | VAF 96/493 reads (19%) | catalogued as COSV57978507; called by muse, mutect2, varscan2
- OR10G7 | c.477C>A p.T159= | Silent (SNP) | VAF 264/399 reads (66%) | catalogued as COSV100389789; called by muse, mutect2, varscan2
- OR10W1 | c.246C>G p.T82= | Silent (SNP) | VAF 141/432 reads (33%) | called by muse, mutect2, varscan2
- OR14C36 | c.21G>A p.V7= | Silent (SNP) | VAF 321/321 reads (100%) | called by muse, mutect2, varscan2
- OR1A2 | c.474C>A p.P158= | Silent (SNP) | VAF 358/359 reads (100%) | catalogued as COSV67936087; called by muse, mutect2, varscan2
- OR2T3 | c.90C>T p.A30= | Silent (SNP) | VAF 325/746 reads (44%) | catalogued as COSV100613138; called by muse, mutect2
- OR5AP2 | c.405C>A p.P135= | Silent (SNP) | VAF 83/270 reads (31%) | catalogued as COSV100266444; called by muse, mutect2, varscan2
- OR5AS1 | c.684C>T p.I228= | Silent (SNP) | VAF 136/459 reads (30%) | catalogued as rs1312393517, COSV100546325; called by muse, mutect2, varscan2
- OR8K5 | c.654C>T p.Y218= | Silent (SNP) | VAF 107/384 reads (28%) | catalogued as COSV100537298; called by muse, mutect2, varscan2
- P2RY8 | c.189C>A p.I63= | Silent (SNP) | VAF 492/968 reads (51%) | catalogued as rs780449772; called by muse, mutect2, varscan2
- PCDHB8 | c.1716C>A p.P572= | Silent (SNP) | VAF 522/578 reads (90%) | called by muse, mutect2
- PCSK1N | c.483C>A p.A161= | Silent (SNP) | VAF 408/840 reads (49%) | called by muse, varscan2
- PDCD1 | c.141G>T p.G47= | Silent (SNP) | VAF 221/641 reads (34%) | called by muse, mutect2, varscan2
- PIGO | c.357G>A p.R119= | Silent (SNP) | VAF 279/279 reads (100%) | catalogued as COSV53052906; called by muse, mutect2, varscan2
- PIK3C2G | c.1734C>T p.V578= | Silent (SNP) | VAF 101/216 reads (47%) | called by muse, mutect2, varscan2
- PLEKHD1 | c.579G>A p.V193= | Silent (SNP) | VAF 132/132 reads (100%) | called by muse, mutect2, varscan2
- PLXDC2 | c.222G>T p.A74= | Silent (SNP) | VAF 253/387 reads (65%) | catalogued as COSV65915709; called by muse, mutect2, varscan2
- PNPLA1 | c.1005T>A p.L335= (on ENST00000394571 / NM_001374623.1; = p.L240= on NM_173676.2) | Silent (SNP) | VAF 317/480 reads (66%) | called by muse, mutect2, varscan2
- POMC | c.7A>C p.R3= | Silent (SNP) | VAF 79/264 reads (30%) | called by muse, mutect2, varscan2
- POPDC2 | c.132C>A p.G44= | Silent (SNP) | VAF 255/255 reads (100%) | called by muse, mutect2, varscan2
- POU3F4 | c.966G>T p.V322= | Silent (SNP) | VAF 163/437 reads (37%) | called by muse, mutect2, varscan2
- PPP2R2B | c.978C>A p.R326= (on ENST00000394409; = p.R392= on NM_181674.2) | Silent (SNP) | VAF 187/188 reads (99%) | called by muse, mutect2, varscan2
- PROP1 | c.294C>A p.A98= | Silent (SNP) | VAF 409/409 reads (100%) | called by muse, mutect2, varscan2
- PRR16 | c.525C>G p.P175= (on ENST00000407149 / NM_001300783.2; = p.P152= on NM_016644.2) | Silent (SNP) | VAF 223/224 reads (100%) | catalogued as rs1278097781, COSV101088305; called by muse, mutect2, varscan2
- PRR32 | c.100C>T p.L34= | Silent (SNP) | VAF 184/644 reads (29%) | called by muse, mutect2
- PRUNE2 | c.2229G>T p.L743= | Silent (SNP) | VAF 136/435 reads (31%) | called by mutect2, varscan2
- PSG9 | c.477G>A p.R159= | Silent (SNP) | VAF 200/285 reads (70%) | catalogued as COSV99392042; called by muse, mutect2, varscan2
- PTH2R | c.762C>A p.I254= | Silent (SNP) | VAF 151/446 reads (34%) | catalogued as COSV55917088; called by muse, mutect2, varscan2
- PTPRF | c.453A>T p.T151= | Silent (SNP) | VAF 216/339 reads (64%) | called by muse, varscan2
- PVRIG | c.583C>A p.R195= | Silent (SNP) | VAF 228/442 reads (52%) | catalogued as rs138822111; called by muse, mutect2, varscan2
- RASSF9 | c.1083C>G p.A361= | Silent (SNP) | VAF 228/477 reads (48%) | called by muse, mutect2, varscan2
82 further variants in this file (0 protein-altering or splice-affecting, 44 silent, 38 other) are not listed here.
